Somatic mutation profile of tumor specimen TCGA-EE-A29V-06A (aliquot TCGA-EE-A29V-06A-12D-A197-08) from TCGA case TCGA-EE-A29V, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 87.1 years (31,805 days).
Specimen TCGA-EE-A29V-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a7e8e97e-f8e7-455f-8560-e92b8064fa66.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EE-A29V-10A (Blood Derived Normal), aliquot TCGA-EE-A29V-10A-01D-A199-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/52163f5b-e137-4b93-bc50-1e2bdbcf6c6f

The open-access MAF lists 1,254 somatic variants for this specimen: 808 protein-altering or splice-affecting, 421 silent, 25 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 733, Silent 421, Nonsense Mutation 34, Splice Region 18, Splice Site 16, Intron 11, RNA 6, 3'UTR 6, Frame Shift Del 5, 5'UTR 2, Nonstop Mutation 1, In Frame Del 1.

Variants (750 of 1,254; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BCL2L12 | c.52C>T p.R18W | Missense Mutation (SNP) | VAF 27/78 reads (35%) | hotspot (GDC flag); SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.796); catalogued as rs1057519880, COSV55862483; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- CDKN2A | c.148C>T p.Q50* | Nonsense Mutation (SNP) | VAF 91/181 reads (50%) | hotspot (GDC flag); catalogued as rs864622636, CM023895, COSV58683786; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CHRNA4 | c.878C>T p.T293I | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs281865066, CM033759, COSV64720275; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CTCF | c.1061C>T p.S354F | Missense Mutation (SNP) | VAF 64/184 reads (35%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV50461395, COSV50462411; called by muse, mutect2, varscan2
- HNF1A | c.599G>A p.R200Q | Missense Mutation (SNP) | VAF 115/353 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.27); catalogued as rs893256143, CM981898, COSV57459659; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- INMT | c.635C>T p.S212F | Missense Mutation (SNP) | VAF 12/29 reads (41%) | hotspot (GDC flag); SIFT tolerated (0.19); PolyPhen benign (0.121); catalogued as rs759141767, COSV50000201; called by muse, mutect2, varscan2
- NOTCH1 | c.928G>A p.G310R | Missense Mutation (SNP) | VAF 13/49 reads (27%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV53032869; called by muse, mutect2, varscan2
- NRAS | c.35G>C p.G12A | Missense Mutation (SNP) | VAF 53/124 reads (43%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.525); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.592G>T p.E198* | Nonsense Mutation (SNP) | VAF 16/25 reads (64%) | hotspot (GDC flag); catalogued as rs1567551854, COSV52678088, COSV52771688, COSV53175941; ClinVar: pathogenic; called by mutect2, varscan2
- ABAT | c.1153G>A p.D385N | Missense Mutation (SNP) | VAF 30/61 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV51625060; called by muse, mutect2, varscan2
- ABCA10 | c.767G>A p.G256E | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV52225509; called by muse, mutect2, varscan2
- AC004593.2 | c.879G>A p.K293= | Splice Region (SNP) | VAF 15/49 reads (31%) | catalogued as rs773777275, COSV56095956; called by muse, mutect2, varscan2
- ACP4 | c.780G>A p.G260= | Splice Region (SNP) | VAF 52/142 reads (37%) | catalogued as COSV54517710; called by muse, mutect2, varscan2
- ACSM2B | c.1720G>A p.A574T | Missense Mutation (SNP) | VAF 75/227 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0.026); catalogued as COSV61658672; called by muse, mutect2, varscan2
- ACTL6B | c.712G>A p.E238K | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT tolerated (0.65); PolyPhen benign (0.007); catalogued as COSV50518032, COSV50518660; called by muse, mutect2, varscan2
- ACTR5 | c.1542G>T p.M514I | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT tolerated (0.38); PolyPhen benign (0.031); catalogued as COSV54761385; called by muse, mutect2, varscan2
- ACVRL1 | c.1329T>A p.C443* | Nonsense Mutation (SNP) | VAF 27/57 reads (47%) | catalogued as COSV66360505; called by muse, mutect2, varscan2
- ADAM28 | c.2230C>G p.P744A | Missense Mutation (SNP) | VAF 29/49 reads (59%) | SIFT deleterious (0.02); PolyPhen benign (0.283); catalogued as COSV56102192; called by muse, mutect2, varscan2
- ADAMTS10 | c.2125G>A p.E709K | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.912); catalogued as rs550588972, COSV54356410; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADAMTS10 | c.698G>A p.R233Q | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.364); catalogued as rs1555741462, COSV54353252; called by muse, mutect2, varscan2
- ADAMTS14 | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 35/82 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs780210737, COSV64600981; called by muse, mutect2, varscan2
- ADAMTS15 | c.2030G>T p.G677V | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV54507393; called by mutect2, varscan2
- ADAMTS18 | c.706T>A p.S236T | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT tolerated (0.6); PolyPhen benign (0.053); catalogued as rs1437973862, COSV51418435; called by muse, varscan2
- ADAMTS20 | c.3648G>A p.W1216* | Nonsense Mutation (SNP) | VAF 7/15 reads (47%) | catalogued as COSV67134393; called by mutect2, varscan2
- ADAMTS9 | c.1766G>A p.G589E | Missense Mutation (SNP) | VAF 104/406 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55779668; called by muse, mutect2, varscan2
- ADAR | c.533C>T p.S178F | Missense Mutation (SNP) | VAF 43/151 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.828); catalogued as COSV52722565; called by muse, mutect2, varscan2
- ADCK1 | c.1331C>T p.A444V | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT tolerated (0.18); PolyPhen benign (0.087); catalogued as COSV53082698; called by muse, mutect2, varscan2
- ADD2 | c.2135C>T p.P712L | Missense Mutation (SNP) | VAF 48/146 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52458525; called by muse, mutect2, varscan2
- ADGRB3 | c.2610C>T p.I870= | Splice Region (SNP) | VAF 35/70 reads (50%) | catalogued as COSV53251158; called by muse, mutect2, varscan2
- ADGRE1 | c.2183C>T p.S728F | Missense Mutation (SNP) | VAF 30/52 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.789); catalogued as rs748162874, COSV51677657; called by muse, mutect2, varscan2
- ADGRF4 | c.1283C>T p.S428F | Missense Mutation (SNP) | VAF 37/69 reads (54%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.914); catalogued as rs1399082727, COSV51954086; called by muse, mutect2, varscan2
- ADGRV1 | c.4385G>A p.G1462E | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV67989180; called by muse, mutect2, varscan2
- ADIPOR1 | c.604C>T p.R202W | Missense Mutation (SNP) | VAF 43/131 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.035); catalogued as rs756988796, COSV61851879; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AGAP1 | c.1979G>A p.R660Q (on ENST00000304032 / NM_001037131.3; = p.R607Q on NM_014914.5) | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV58331487; called by muse, mutect2, varscan2
- AGBL5 | c.1216C>T p.P406S | Missense Mutation (SNP) | VAF 25/115 reads (22%) | SIFT tolerated (0.39); PolyPhen benign (0.015); catalogued as COSV59936166; called by muse, mutect2, varscan2
- AGBL5 | c.1217C>T p.P406L | Missense Mutation (SNP) | VAF 26/117 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.243); catalogued as COSV100549485; called by muse, mutect2, varscan2
- AGRN | c.2312A>G p.Y771C | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV101039175; called by muse, mutect2
- AIFM3 | c.1415C>T p.P472L | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV99302413; called by muse, mutect2, varscan2
- AKAP12 | c.1826C>T p.P609L | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV53574005; called by muse, mutect2, varscan2
- AKAP6 | c.829G>A p.V277I | Missense Mutation (SNP) | VAF 43/140 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.054); catalogued as COSV55220246; called by muse, mutect2, varscan2
- AKR1C4 | c.224A>G p.K75R | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.243); catalogued as COSV54124018; called by muse, mutect2, varscan2
- AMOT | c.2402A>T p.H801L (on ENST00000371959 / NM_001113490.1; = p.H392L on NM_133265.3) | Missense Mutation (SNP) | VAF 46/64 reads (72%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV59065459; called by muse, varscan2
- AMPH | c.1672G>A p.E558K | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.079); catalogued as rs372537853; called by muse, mutect2, varscan2
- ANAPC4 | c.1133C>T p.P378L | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.516); catalogued as COSV59544913; called by muse, mutect2
- ANGPTL7 | c.902C>T p.S301F | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100816788; called by muse, mutect2, varscan2
- ANK2 | c.9913C>T p.P3305S | Missense Mutation (SNP) | VAF 28/96 reads (29%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.015); catalogued as COSV52144641; called by muse, mutect2, varscan2
- ANK3 | c.5690C>T p.S1897F | Missense Mutation (SNP) | VAF 30/65 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.853); catalogued as COSV55045495, COSV55046905; called by muse, varscan2
- ANKFN1 | c.268C>T p.P90S | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); catalogued as rs777160054, COSV59446441; called by muse, mutect2, varscan2
- ANKMY1 | c.755C>T p.P252L | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.79); PolyPhen benign (0.003); catalogued as COSV56036763; called by muse, mutect2, varscan2
- ANKRD11 | c.7447C>T p.L2483F | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV56364324; called by muse, mutect2, varscan2
- ANKRD45 | c.563G>A p.G188E | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.17); catalogued as COSV60960601; called by muse, mutect2, varscan2
- ANKRD45 | c.562G>A p.G188R | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.284); catalogued as COSV100322742; called by muse, mutect2, varscan2
- ANKZF1 | c.671+1G>A p.X224_splice | Splice Site (SNP) | VAF 35/106 reads (33%) | catalogued as COSV55477359; called by muse, mutect2, varscan2
- AOAH | c.712C>T p.P238S | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as COSV51744898; called by muse, mutect2, varscan2
- AOC1 | c.472G>C p.A158P | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.807); catalogued as COSV62869602; called by muse, mutect2, varscan2
- AP002512.3 | c.817G>A p.G273R | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.99); catalogued as COSV54406583; called by muse, mutect2, varscan2
- APC2 | c.2326G>A p.G776S | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.984); catalogued as COSV52019950; called by muse, mutect2, varscan2
- APOBEC3B | c.847C>T p.P283S | Missense Mutation (SNP) | VAF 26/103 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV100213885; called by muse, mutect2, varscan2
- APOBEC3B | c.848C>T p.P283L | Missense Mutation (SNP) | VAF 27/102 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100213887; called by muse, mutect2, varscan2
- ARFGEF2 | c.1177C>T p.P393S | Missense Mutation (SNP) | VAF 33/80 reads (41%) | SIFT tolerated (0.2); PolyPhen benign (0.155); catalogued as COSV64213405; called by muse, mutect2, varscan2
- ARHGEF17 | c.3124C>T p.P1042S | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.41); PolyPhen benign (0.022); catalogued as rs1278771898, COSV55234379; called by muse, mutect2, varscan2
- ARHGEF17 | c.4846G>A p.G1616S | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as rs761435260, COSV55234389; called by muse, mutect2, varscan2
- ARID5A | c.258G>A p.Q86= | Splice Region (SNP) | VAF 15/62 reads (24%) | catalogued as COSV62591405, COSV62591492; called by muse, mutect2, varscan2
- ARID5B | c.65A>T p.Y22F | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54423917; called by muse, mutect2, varscan2
- ARMCX1 | c.461C>T p.P154L | Missense Mutation (SNP) | VAF 28/38 reads (74%) | SIFT deleterious (0.01); PolyPhen benign (0.076); catalogued as COSV65705324; called by muse, mutect2
- ASB15 | c.331G>A p.G111R | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV51927220; called by muse, mutect2, varscan2
- ATF6 | c.1429C>T p.L477F | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as COSV63407148; called by muse, mutect2, varscan2
- ATP13A5 | c.2098G>A p.E700K | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.85); catalogued as COSV100665905, COSV60867553; called by muse, mutect2, varscan2
- ATP1A3 | c.1631C>T p.A544V (on ENST00000545399 / NM_001256214.2; = p.A531V on NM_152296.5) | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.212); catalogued as COSV57489019; called by muse, mutect2, varscan2
- ATP2A2 | c.58G>A p.E20K | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT tolerated (0.3); PolyPhen benign (0.101); catalogued as COSV58045661; called by mutect2, varscan2
- ATP6V0A4 | c.2114G>A p.G705E | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0.025); catalogued as COSV100023745, COSV59477502; called by muse, mutect2, varscan2
- ATP8A1 | c.1349C>T p.S450L | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.32); PolyPhen benign (0.099); catalogued as COSV52539617; called by muse, mutect2, varscan2
- AVPR1B | c.8C>T p.S3F | Missense Mutation (SNP) | VAF 82/252 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0.154); catalogued as COSV65638318; called by muse, mutect2, varscan2
- BARD1 | c.1304C>T p.A435V | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV53613680; called by muse, mutect2, varscan2
- BCL2A1 | c.61C>A p.L21I | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.678); catalogued as COSV99144381; called by muse, mutect2, varscan2
- BCL2L11 | c.187C>T p.P63S | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.994); catalogued as rs1386206200, COSV58030979; called by muse, mutect2, varscan2
- BCL2L13 | c.1138C>T p.L380F | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.007); catalogued as COSV58226532; called by muse, mutect2, varscan2
- BCORL1 | c.736C>T p.P246S | Missense Mutation (SNP) | VAF 46/61 reads (75%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as COSV54400005; called by muse, mutect2, varscan2
- BDP1 | c.5888C>T p.P1963L | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs549534181, COSV100702824, COSV62432448; called by muse, mutect2, varscan2
- BPTF | c.9047G>T p.C3016F | Missense Mutation (SNP) | VAF 42/83 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58840671; called by muse, mutect2, varscan2
- BRINP1 | c.304C>T p.Q102* | Nonsense Mutation (SNP) | VAF 19/46 reads (41%) | catalogued as COSV56291369; called by muse, mutect2, varscan2
- BRINP3 | c.1967G>A p.R656Q | Missense Mutation (SNP) | VAF 32/90 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as rs149389696; called by muse, mutect2, varscan2
- BTNL8 | c.1070T>G p.V357G | Missense Mutation (SNP) | VAF 20/33 reads (61%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV51459742; called by muse, mutect2, varscan2
- C15orf39 | c.2062C>T p.P688S | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV62297228; called by muse, mutect2, varscan2
- C19orf53 | c.262G>A p.G88R | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.127); catalogued as rs1484297557, COSV55606217; called by muse, mutect2, varscan2
- C2CD3 | c.4255C>T p.H1419Y | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.606); catalogued as rs1352857135, COSV58095113; called by muse, mutect2, varscan2
- C4BPA | c.1744G>A p.E582K | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0.045); catalogued as COSV65536785; called by muse, mutect2, varscan2
- C5AR2 | c.821C>T p.P274L | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV57256650; called by muse, mutect2, varscan2
- C9orf50 | c.808C>T p.P270S | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs538755244, COSV65252662; called by muse, mutect2, varscan2
- CABP7 | c.256G>A p.D86N | Missense Mutation (SNP) | VAF 19/35 reads (54%) | SIFT tolerated (0.35); PolyPhen probably damaging (1); catalogued as COSV53363427; called by muse, mutect2, varscan2
- CACNA1C | c.334C>T p.P112S | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59739807; called by muse, mutect2, varscan2
- CACNA1S | c.5102G>A p.G1701E | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); catalogued as COSV62941284; called by muse, mutect2, varscan2
- CACNA1S | c.2663G>A p.S888N | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.402); catalogued as COSV62941291; called by muse, mutect2, varscan2
- CACNA2D3 | c.1639A>G p.K547E | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.297); catalogued as COSV55554963; called by muse, mutect2, varscan2
- CACNB2 | c.1714G>A p.E572K (on ENST00000324631 / NM_201596.3; = p.E517K on NM_000724.4) | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.155); catalogued as rs539824188, COSV56634203; called by muse, mutect2, varscan2
- CALB1 | c.730G>A p.G244R | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as COSV55368325; called by muse, mutect2, varscan2
- CAMK2G | c.701C>T p.P234L | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV59482249; called by muse, mutect2, varscan2
- CAMSAP2 | c.1373G>A p.G458E (on ENST00000236925 / NM_001297707.2; = p.G447E on NM_203459.3) | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.365); catalogued as rs1273986882, COSV52673268; called by muse, mutect2, varscan2
- CAMTA1 | c.1430C>T p.P477L | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV57910660; called by muse, mutect2, varscan2
- CARD11 | c.2990G>A p.G997D | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.493); catalogued as rs1334146426, COSV101211075; called by muse, mutect2, varscan2
- CARD11 | c.2989G>A p.G997S | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT tolerated (0.57); PolyPhen probably damaging (0.93); catalogued as COSV101210997; called by muse, mutect2, varscan2
- CARS2 | c.1052C>T p.S351L | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); catalogued as COSV57287217; called by muse, mutect2, varscan2
- CCDC117 | c.652C>T p.L218F | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.982); catalogued as rs1274941880, COSV50770883, COSV99968946; called by muse, mutect2, varscan2
- CCDC122 | c.470A>G p.D157G | Missense Mutation (SNP) | VAF 29/73 reads (40%) | SIFT tolerated (0.16); PolyPhen benign (0.033); catalogued as COSV55709714; called by muse, mutect2, varscan2
- CCDC61 | c.469G>A p.E157K | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.915); catalogued as COSV54429294; called by muse, mutect2, varscan2
- CCDC80 | c.2617G>A p.G873R | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1239346844, COSV52818060; called by muse, mutect2, varscan2
- CCDC81 | c.1817+1G>A p.X606_splice (on ENST00000445632 / NM_001156474.2; = p.X516_splice on NM_021827.4) | Splice Site (SNP) | VAF 20/65 reads (31%) | catalogued as rs773774608, COSV53579569; called by muse, mutect2, varscan2
- CCDC92 | c.491C>T p.A164V | Missense Mutation (SNP) | VAF 28/60 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV53020503; called by muse, mutect2, varscan2
- CCIN | c.946C>T p.R316W | Missense Mutation (SNP) | VAF 18/29 reads (62%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); catalogued as rs765562220, COSV58725046; called by muse, mutect2, varscan2
- CCNDBP1 | c.249G>A p.Q83= | Splice Region (SNP) | VAF 6/12 reads (50%) | catalogued as COSV99543940; called by muse, mutect2
- CCNDBP1 | c.249+1G>A p.X83_splice | Splice Site (SNP) | VAF 6/12 reads (50%) | catalogued as COSV99543943; called by muse, mutect2, varscan2
- CD163L1 | c.1296G>A p.W432* | Nonsense Mutation (SNP) | VAF 15/53 reads (28%) | catalogued as COSV58014963; called by muse, mutect2, varscan2
- CD1B | c.751G>A p.G251R | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.627); catalogued as COSV63804594, COSV63804943; called by muse, varscan2
- CD22 | c.1054C>T p.L352F | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.474); catalogued as COSV50050448, COSV50057450; called by muse, mutect2, varscan2
- CD248 | c.1337C>T p.S446F | Missense Mutation (SNP) | VAF 39/112 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.887); catalogued as COSV60937027; called by muse, mutect2, varscan2
- CDC42BPB | c.505G>T p.E169* | Nonsense Mutation (SNP) | VAF 18/32 reads (56%) | catalogued as COSV63475783; called by muse, mutect2, varscan2
- CDH16 | c.1772C>T p.P591L | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as COSV55337766; called by muse, mutect2, varscan2
- CDH23 | c.6457C>T p.P2153S | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.163); catalogued as COSV56473973, COSV99820428; called by muse, mutect2, varscan2
- CDK4 | c.749C>A p.P250H | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as COSV99226151; called by mutect2, varscan2
- CDYL2 | c.1390del p.R464Gfs*4 | Frame Shift Del (DEL) | VAF 45/137 reads (33%) | catalogued as COSV73654985; called by mutect2, pindel, varscan2
- CEMIP | c.238G>A p.G80R | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99587462; called by muse, mutect2, varscan2
- CEMIP | c.239G>A p.G80E | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99587463; called by muse, mutect2, varscan2
- CEP162 | c.3700C>A p.L1234I | Missense Mutation (SNP) | VAF 31/46 reads (67%) | SIFT tolerated (0.15); PolyPhen benign (0.168); catalogued as COSV57621494, COSV57622914; called by muse, mutect2, varscan2
- CEP78 | c.1867C>T p.P623S (on ENST00000424347 / NM_001349840.2; = p.P624S on NM_032171.3) | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.001); catalogued as rs948492353, COSV52848648; called by muse, mutect2, varscan2
- CES1 | c.505C>T p.Q169* | Nonsense Mutation (SNP) | VAF 11/78 reads (14%) | catalogued as COSV62087044; called by muse, mutect2, varscan2
- CFH | c.3549G>A p.W1183* | Nonsense Mutation (SNP) | VAF 33/82 reads (40%) | catalogued as CM070673, CM103324, COSV66410361; called by muse, mutect2, varscan2
- CHD5 | c.1935G>A p.R645= | Splice Region (SNP) | VAF 31/79 reads (39%) | catalogued as COSV52418930; called by muse, mutect2, varscan2
- CHD7 | c.3196C>T p.P1066S | Missense Mutation (SNP) | VAF 68/176 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.029); catalogued as COSV71112434; called by muse, mutect2, varscan2
- CHRD | c.2638C>T p.P880S | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.554); catalogued as COSV52609716; called by muse, mutect2, varscan2
- CHRNA9 | c.676G>A p.D226N | Missense Mutation (SNP) | VAF 108/291 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV59574993; called by muse, mutect2, varscan2
- CHST12 | c.608C>T p.P203L | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1003931693, COSV51676440, COSV99324297; called by muse, mutect2, varscan2
- CLASP1 | c.3971C>T p.A1324V | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.437); catalogued as COSV55329258; called by muse, mutect2, varscan2
- CLCN1 | c.1216T>A p.F406I | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV58371491; called by muse, mutect2, varscan2
- CLCN7 | c.981C>T p.I327= | Splice Region (SNP) | VAF 15/52 reads (29%) | catalogued as rs776917548, COSV51971756; called by muse, mutect2, varscan2
- CLEC5A | c.359A>G p.D120G | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.355); catalogued as rs782346936, COSV69397561; called by muse, mutect2, varscan2
- CLN6 | c.403C>T p.H135Y | Missense Mutation (SNP) | VAF 32/97 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); catalogued as rs1449019695, COSV51117240; called by muse, mutect2, varscan2
- CLPTM1 | c.1439C>T p.S480F | Missense Mutation (SNP) | VAF 86/212 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV61612333; called by muse, mutect2, varscan2
- CLSTN2 | c.1007C>T p.S336F | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.459); catalogued as COSV71722200; called by muse, varscan2
- CLTCL1 | c.1034C>T p.P345L | Missense Mutation (SNP) | VAF 41/120 reads (34%) | SIFT tolerated (0.61); PolyPhen benign (0.044); catalogued as COSV54229669; called by muse, mutect2, varscan2
- CLVS2 | c.277G>A p.D93N | Missense Mutation (SNP) | VAF 24/48 reads (50%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.479); catalogued as rs765718594, COSV51565277; called by muse, mutect2, varscan2
- CNTNAP4 | c.2897G>A p.G966E | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.599); catalogued as COSV100273770; called by muse, mutect2, varscan2
- CNTNAP5 | c.641G>A p.G214E | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.021); catalogued as COSV101444235, COSV70494453; called by muse, mutect2, varscan2
- COL11A1 | c.3233G>A p.G1078E | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100618352; called by muse, mutect2, varscan2
- COL11A1 | c.3232G>A p.G1078R | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62190299; called by muse, mutect2, varscan2
- COL13A1 | c.527C>T p.P176L (on ENST00000398978 / NM_001130103.2; = p.P138L on NM_080798.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs751746018, COSV62571746; called by muse, mutect2, varscan2
- COL22A1 | c.2518G>A p.G840S | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100277192, COSV57345150; called by muse, mutect2, varscan2
- COL27A1 | c.2644C>T p.P882S | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV61928037; called by muse, mutect2, varscan2
- COL4A1 | c.1883C>T p.S628F | Missense Mutation (SNP) | VAF 55/162 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.034); catalogued as rs1468687240, COSV65425834; called by muse, mutect2, varscan2
- COL5A3 | c.3666+1G>A p.X1222_splice | Splice Site (SNP) | VAF 21/51 reads (41%) | catalogued as COSV53413771; called by muse, mutect2, varscan2
- COL6A2 | c.1771G>A p.E591K | Missense Mutation (SNP) | VAF 41/91 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.792); catalogued as COSV56009719; called by muse, mutect2, varscan2
- COL6A6 | c.1025G>A p.R342Q | Missense Mutation (SNP) | VAF 33/120 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.538); catalogued as rs368728937; called by muse, mutect2, varscan2
- COL6A6 | c.5074G>A p.G1692R | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62029601; called by muse, mutect2, varscan2
- CPAMD8 | c.3820T>C p.F1274L (on ENST00000651564; = p.F1227L on NM_015692.5) | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.993); catalogued as COSV71596820; called by muse, mutect2, varscan2
- CPNE1 | c.299C>T p.S100F (on ENST00000352393; = p.S105F on NM_003915.5) | Missense Mutation (SNP) | VAF 32/95 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.006); catalogued as COSV58292880; called by muse, mutect2, varscan2
- CPS1 | c.643G>A p.G215R | Missense Mutation (SNP) | VAF 26/102 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as COSV51815451; called by muse, mutect2, varscan2
- CR1 | c.5381C>T p.P1794L | Missense Mutation (SNP) | VAF 34/80 reads (43%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as COSV65459797; called by muse, mutect2, varscan2
- CRB1 | c.146C>T p.S49L | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT tolerated (0.71); PolyPhen benign (0.203); catalogued as COSV66343857; called by muse, mutect2, varscan2
- CSMD3 | c.6436G>A p.G2146S (on ENST00000297405 / NM_001363185.1; = p.G2042S on NM_052900.3) | Missense Mutation (SNP) | VAF 50/77 reads (65%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.889); catalogued as COSV52099534, COSV52230668; called by muse, varscan2
- CTAGE6 | c.694G>A p.E232K | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.444); catalogued as rs1156834063, COSV101417900; called by mutect2, varscan2
- CTNNA2 | c.2032G>A p.E678K | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT tolerated (0.07); PolyPhen benign (0.377); catalogued as COSV58161888; called by muse, mutect2, varscan2
- CTTNBP2NL | c.455C>T p.S152F | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.989); catalogued as rs1483529545, COSV54745468; called by muse, mutect2, varscan2
- CUEDC2 | c.656+1G>A p.X219_splice | Splice Site (SNP) | VAF 17/39 reads (44%) | catalogued as rs762999951, COSV50048737; called by muse, mutect2, varscan2
- CYLC1 | c.296C>T p.P99L | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.25); catalogued as COSV61413987; called by muse, mutect2
- CYP2C8 | c.985C>T p.H329Y | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.199); catalogued as rs1323706553, COSV64877859; called by muse, mutect2, varscan2
- CYP3A5 | c.383G>A p.R128K | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.798); catalogued as COSV56121235, COSV99770058; called by muse, mutect2, varscan2
- CYP4F11 | c.1115G>A p.W372* | Nonsense Mutation (SNP) | VAF 8/44 reads (18%) | catalogued as rs1253003146, COSV56128065; called by muse, mutect2, varscan2
- DAGLA | c.271C>T p.R91C | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV57194037; called by muse, mutect2, varscan2
- DAOA | c.163G>A p.V55I | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0); catalogued as COSV61602852; called by mutect2, varscan2
- DARS1 | c.481C>T p.R161W | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs779321480, COSV51539557; called by muse, mutect2, varscan2
- DBX1 | c.935C>T p.S312L | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.9); catalogued as rs763778118, COSV57054453; called by muse, mutect2, varscan2
- DCX | c.827G>A p.G276E | Missense Mutation (SNP) | VAF 38/51 reads (75%) | SIFT tolerated (0.36); PolyPhen benign (0.024); catalogued as COSV57571649; called by muse, mutect2, varscan2
- DDX50 | c.482T>A p.F161Y | Missense Mutation (SNP) | VAF 50/112 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV65292750; called by muse, varscan2
- DDX50 | c.616A>G p.I206V | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT tolerated (0.28); PolyPhen benign (0.102); catalogued as rs1564602212, COSV65292752; called by muse, varscan2
- DDX60 | c.1340-1G>A p.X447_splice | Splice Site (SNP) | VAF 9/20 reads (45%) | catalogued as COSV67097601; called by muse, mutect2, varscan2
- DENND1A | c.91C>T p.P31S | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs1564280514, COSV101010840; called by muse, mutect2, varscan2
- DENND4B | c.3247C>T p.P1083S | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV63410314; called by muse, mutect2
- DGKB | c.1612G>A p.G538S | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99344334; called by muse, mutect2, varscan2
- DGKK | c.2447G>A p.R816Q | Missense Mutation (SNP) | VAF 47/63 reads (75%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs782545441, COSV65708298, COSV65709338; called by muse, mutect2, varscan2
- DHX37 | c.2245C>T p.P749S | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT tolerated (0.49); PolyPhen benign (0.056); catalogued as COSV58136427; called by muse, mutect2, varscan2
- DIDO1 | c.3914C>T p.S1305L | Missense Mutation (SNP) | VAF 39/138 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.162); catalogued as rs762356761, COSV56615969; called by muse, mutect2, varscan2
- DKC1 | c.625C>T p.P209S | Missense Mutation (SNP) | VAF 40/54 reads (74%) | SIFT tolerated (0.18); PolyPhen benign (0.065); catalogued as COSV65777759; called by muse, mutect2, varscan2
- DLEC1 | c.1001C>T p.P334L | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.969); catalogued as rs1267308656, COSV57302093; called by muse, mutect2, varscan2
- DLGAP1 | c.1591+1G>A p.X531_splice | Splice Site (SNP) | VAF 9/22 reads (41%) | catalogued as COSV59816354, COSV59823122; called by muse, mutect2, varscan2
- DLGAP1 | c.775T>G p.C259G | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.088); catalogued as COSV59816385; called by muse, mutect2, varscan2
- DLGAP5 | c.665C>T p.S222F | Missense Mutation (SNP) | VAF 25/117 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as COSV55963970; called by muse, mutect2, varscan2
- DMBT1 | c.5065G>A p.G1689R (on ENST00000338354 / NM_001377530.1; = p.G932R on NM_004406.3) | Missense Mutation (SNP) | VAF 68/201 reads (34%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as COSV57549922, COSV57551783; called by muse, mutect2, varscan2
- DNAH11 | c.8017C>T p.P2673S | Missense Mutation (SNP) | VAF 25/106 reads (24%) | SIFT tolerated (0.39); PolyPhen benign (0.077); catalogued as COSV60964919; called by muse, mutect2, varscan2
- DNAH3 | c.5959G>A p.D1987N | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV54527448; called by muse, mutect2, varscan2
- DNAH3 | c.5345C>T p.S1782L | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.477); catalogued as COSV54532469; called by muse, mutect2, varscan2
- DNAH5 | c.7778G>A p.G2593E | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54236569; called by muse, mutect2, varscan2
- DNAH7 | c.5380G>A p.V1794I | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV56772696; called by muse, mutect2, varscan2
- DNAH7 | c.2110G>A p.E704K | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.086); catalogued as COSV56772709; called by muse, mutect2, varscan2
- DNAJA4 | c.651G>A p.M217I (on ENST00000343789; = p.M246I on NM_018602.3) | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); catalogued as COSV59426201; called by muse, mutect2, varscan2
- DOCK2 | c.4555G>A p.D1519N | Missense Mutation (SNP) | VAF 28/42 reads (67%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV56959784; called by muse, varscan2
- DOCK3 | c.5630G>A p.G1877D | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT tolerated, low confidence (0.39); PolyPhen possibly damaging (0.502); catalogued as COSV56532154; called by muse, mutect2, varscan2
- DOK5 | c.259G>A p.D87N | Missense Mutation (SNP) | VAF 32/101 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.051); catalogued as rs751913418, COSV52822329; called by muse, mutect2, varscan2
- DPY19L4 | c.2159C>T p.S720F | Missense Mutation (SNP) | VAF 94/292 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs140198354, COSV68963253; called by muse, mutect2, varscan2
- DRD3 | c.854C>T p.S285F | Missense Mutation (SNP) | VAF 60/175 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.789); catalogued as rs374601195; called by muse, mutect2, varscan2
- DRGX | c.581C>T p.P194L | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65136683; called by muse, mutect2, varscan2
- DSC2 | c.1648C>T p.L550F | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.127); catalogued as COSV51866560; called by muse, mutect2, varscan2
- DSG2 | c.466G>A p.E156K | Missense Mutation (SNP) | VAF 31/62 reads (50%) | SIFT tolerated (0.34); PolyPhen benign (0.005); catalogued as rs566251077, COSV55200443; called by muse, mutect2, varscan2
- DTNBP1 | c.385G>A p.E129K | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59040694, COSV59041724; called by muse, mutect2, varscan2
- DTX4 | c.292G>C p.D98H | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV57091470, COSV57092379; called by muse, mutect2, varscan2
- DUSP22 | c.518G>A p.G173E | Missense Mutation (SNP) | VAF 35/164 reads (21%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.129); catalogued as COSV60528571; called by muse, mutect2, varscan2
- DUXA | c.263G>A p.G88E | Missense Mutation (SNP) | VAF 31/79 reads (39%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.998); catalogued as COSV73729773; called by muse, mutect2, varscan2
- DYSF | c.311C>T p.P104L | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.334); catalogued as COSV50464242; called by muse, mutect2, varscan2
- EDNRA | c.584G>A p.G195E | Missense Mutation (SNP) | VAF 35/105 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60098608; called by muse, mutect2, varscan2
- EDRF1 | c.2488C>T p.P830S (on ENST00000356792 / NM_001202438.2; = p.P796S on NM_015608.2) | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT tolerated (0.39); PolyPhen benign (0.015); catalogued as COSV61762976; called by muse, mutect2, varscan2
- EFCAB7 | c.1856G>A p.W619* | Nonsense Mutation (SNP) | VAF 8/33 reads (24%) | catalogued as rs548423707, COSV64314931; called by muse, mutect2, varscan2
- EIF3B | c.2023C>T p.H675Y | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.352); catalogued as rs1312430252, COSV62803885; called by muse, mutect2, varscan2
- EIF4B | c.994C>T p.P332S | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.957); catalogued as COSV50404621; called by muse, mutect2, varscan2
- EIF4ENIF1 | c.1123C>T p.P375S | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.764); catalogued as COSV57516793; called by muse, mutect2, varscan2
- EIF5B | c.2939G>A p.G980E | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56814430; called by muse, mutect2, varscan2
- ELK4 | c.470C>T p.S157F | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.332); catalogued as COSV56985377; called by muse, mutect2, varscan2
- ELL | c.1745A>G p.K582R | Missense Mutation (SNP) | VAF 88/154 reads (57%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV53213802; called by muse, varscan2
- EML3 | c.473C>T p.S158F | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as rs760561968, COSV53883199; called by muse, mutect2, varscan2
- EML3 | c.289C>T p.P97S | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV99606185; called by muse, mutect2
- EMSY | c.3344C>T p.T1115I | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.017); catalogued as COSV58262986; called by muse, mutect2, varscan2
- ENPEP | c.173C>T p.S58F | Missense Mutation (SNP) | VAF 34/88 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.372); catalogued as rs868690232, COSV54453439; called by muse, mutect2, varscan2
- ENTPD5 | c.1287A>G p.*429Wext*22 | Nonstop Mutation (SNP) | VAF 23/50 reads (46%) | catalogued as COSV99474258; called by muse, mutect2, varscan2
- EPB41 | c.254C>T p.S85L | Missense Mutation (SNP) | VAF 38/101 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); catalogued as rs561329874, COSV58049880; called by muse, mutect2, varscan2
- EPB41L5 | c.1264T>G p.S422A | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT tolerated (0.36); PolyPhen benign (0.01); catalogued as COSV55354286; called by muse, mutect2, varscan2
- EPHA7 | c.2440A>C p.T814P | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as COSV65186427; called by muse, mutect2, varscan2
- EPHB4 | c.1402G>A p.E468K | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.852); catalogued as rs977239511, COSV62269567; called by mutect2, varscan2
- EPS8L3 | c.970-1G>A p.X324_splice | Splice Site (SNP) | VAF 5/15 reads (33%) | catalogued as COSV62609867; called by muse, mutect2
- EPX | c.554G>A p.W185* | Nonsense Mutation (SNP) | VAF 15/40 reads (38%) | catalogued as COSV56597314; called by muse, mutect2, varscan2
- ERAL1 | c.52G>A p.V18I | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as rs566231746, COSV54740292; called by muse, mutect2, varscan2
- ERICH3 | c.595C>T p.P199S | Missense Mutation (SNP) | VAF 30/72 reads (42%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.87); catalogued as COSV100445494, COSV58611100; called by muse, mutect2, varscan2
- ERMN | c.604C>T p.R202* | Nonsense Mutation (SNP) | VAF 30/84 reads (36%) | catalogued as rs753504238, COSV101263016, COSV68075466; called by muse, mutect2, varscan2
- ERO1B | c.656C>T p.P219L | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.953); catalogued as COSV59242909; called by muse, mutect2, varscan2
- ETAA1 | c.1076C>T p.S359F | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.031); catalogued as COSV55473946; called by muse, mutect2, varscan2
- ETV5 | c.8G>A p.G3E | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV60503863; called by muse, mutect2, varscan2
- EVI5L | c.23C>T p.P8L | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54486757; called by muse, mutect2, varscan2
- F13B | c.98G>A p.G33E | Missense Mutation (SNP) | VAF 68/192 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66373340, COSV66374568; called by muse, mutect2, varscan2
- F5 | c.47C>T p.T16I | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0.014); catalogued as rs1271328618, COSV55254341; called by muse, mutect2, varscan2
- FAM102A | c.509C>T p.S170F (on ENST00000373095 / NM_001035254.3; = p.S28F on NM_203305.2) | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.259); catalogued as rs368235769; called by muse, varscan2
- FAM135B | c.4135G>A p.G1379S | Missense Mutation (SNP) | VAF 68/288 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52724390, COSV52728224; called by muse, mutect2, varscan2
- FAM135B | c.3328G>A p.G1110R | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as COSV52736548; called by muse, mutect2, varscan2
- FAM160B2 | c.1193C>T p.A398V | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.27); PolyPhen benign (0.114); catalogued as COSV57159211; called by muse, mutect2, varscan2
- FAM47A | c.1856G>A p.G619E | Missense Mutation (SNP) | VAF 24/34 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV60498022; called by muse, mutect2, varscan2
- FAM47B | c.412G>A p.G138R | Missense Mutation (SNP) | VAF 25/31 reads (81%) | SIFT deleterious (0.04); PolyPhen benign (0.255); catalogued as COSV61455281; called by muse, mutect2, varscan2
- FAM76A | c.484C>T p.R162C | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.707); catalogued as rs1018915604, COSV50549091; called by muse, mutect2, varscan2
- FANCA | c.3244C>T p.L1082F | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV59797268; called by muse, mutect2
- FAT3 | c.4979C>T p.S1660F | Missense Mutation (SNP) | VAF 138/435 reads (32%) | SIFT tolerated (0.84); PolyPhen probably damaging (0.977); catalogued as COSV53082047; called by muse, mutect2, varscan2
- FAT4 | c.7792G>A p.G2598R | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100630882, COSV58694347; called by muse, mutect2, varscan2
- FCF1 | c.586C>T p.P196S | Missense Mutation (SNP) | VAF 42/75 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs1268388114, COSV62044243; called by muse, mutect2, varscan2
- FCRL5 | c.970G>A p.E324K | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT tolerated (0.79); PolyPhen benign (0.137); catalogued as COSV100708446, COSV62516624; called by muse, mutect2, varscan2
- FER1L6 | c.2369G>A p.S790N | Missense Mutation (SNP) | VAF 26/104 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV67551200; called by muse, mutect2, varscan2
- FFAR3 | c.50T>C p.V17A | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV100588326; called by muse, mutect2, varscan2
- FHDC1 | c.1634C>T p.P545L | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV52601150; called by muse, mutect2, varscan2
- FLG | c.5753T>C p.V1918A | Missense Mutation (SNP) | VAF 58/190 reads (31%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.973); catalogued as COSV64244036; called by muse, mutect2, varscan2
- FLNC | c.5369C>T p.P1790L | Missense Mutation (SNP) | VAF 46/112 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV57949866; called by muse, mutect2, varscan2
- FMN2 | c.2012G>A p.G671E | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as COSV60438239; called by muse, mutect2, varscan2
- FMNL2 | c.545C>T p.P182L | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.994); catalogued as COSV56498435; called by muse, mutect2, varscan2
- FN1 | c.1817C>T p.P606L | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.103); catalogued as COSV60557047; called by muse, mutect2, varscan2
- FNBP1L | c.1357G>A p.E453K (on ENST00000271234 / NM_001164473.2; = p.E395K on NM_017737.5) | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.287); catalogued as COSV53094524; called by muse, mutect2, varscan2
- FNDC1 | c.1858C>T p.P620S | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT tolerated, low confidence (0.75); PolyPhen benign (0); catalogued as rs779254555, COSV51941943; called by muse, mutect2, varscan2
- FNDC3B | c.1441C>A p.P481T | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100395184; called by muse, mutect2, varscan2
- FNDC3B | c.1442C>T p.P481L | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV100395186; called by muse, mutect2, varscan2
- FOCAD | c.386C>T p.T129I | Missense Mutation (SNP) | VAF 24/38 reads (63%) | SIFT tolerated (0.07); PolyPhen benign (0.191); catalogued as rs376862300; called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.1699C>T p.P567S | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.984); catalogued as COSV58558862; called by muse, mutect2, varscan2
- FRAS1 | c.10720G>A p.G3574R | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as rs1234251198, COSV99356654; called by muse, mutect2
- FRY | c.3849C>T p.I1283= | Splice Region (SNP) | VAF 14/60 reads (23%) | catalogued as COSV66573359; called by muse, mutect2, varscan2
- FRY | c.7985C>T p.S2662L | Missense Mutation (SNP) | VAF 36/100 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.022); catalogued as rs750020821, COSV66573367; called by muse, mutect2, varscan2
- FSHR | c.358C>T p.P120S | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1321110015, COSV100438346; called by muse, mutect2, varscan2
- FUT2 | c.89A>T p.Q30L | Missense Mutation (SNP) | VAF 41/142 reads (29%) | SIFT tolerated, low confidence (0.14); PolyPhen possibly damaging (0.524); catalogued as COSV67179497; called by muse, mutect2, varscan2
- GABPB2 | c.1208C>T p.T403I | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.131); catalogued as rs750051024, COSV64461126; called by muse, mutect2, varscan2
- GABRP | c.40C>T p.L14F | Missense Mutation (SNP) | VAF 21/41 reads (51%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV54663859; called by muse, mutect2, varscan2
- GAD1 | c.124A>G p.K42E | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.034); catalogued as COSV60153077; called by muse, mutect2, varscan2
- GALNT13 | c.1060C>T p.P354S | Missense Mutation (SNP) | VAF 53/149 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.15); catalogued as COSV67215769; called by muse, mutect2, varscan2
- GAPDHS | c.430G>A p.E144K | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.007); catalogued as COSV55883120; called by muse, mutect2, varscan2
- GARRE1 | c.1793C>T p.P598L | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV100209853; called by muse, mutect2, varscan2
- GAS6 | c.1358G>A p.G453E | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.54); catalogued as COSV59847155; called by muse, mutect2, varscan2
- GAS6 | c.1357G>A p.G453R | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.982); catalogued as rs578008516, COSV100582360; called by muse, mutect2, varscan2
- GCN1 | c.1834C>G p.L612V | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT tolerated (0.19); PolyPhen benign (0.175); catalogued as COSV56110343; called by muse, mutect2, varscan2
- GEM | c.584T>G p.L195* | Nonsense Mutation (SNP) | VAF 39/58 reads (67%) | catalogued as COSV52597970; called by muse, mutect2, varscan2
- GET4 | c.410C>T p.S137F | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as COSV56255536; called by muse, mutect2, varscan2
- GLRA3 | c.821C>T p.S274L | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs771115012, COSV56857256; called by muse, mutect2, varscan2
- GMPPB | c.768G>A p.V256= | Splice Region (SNP) | VAF 18/60 reads (30%) | catalogued as COSV57539209; called by muse, mutect2, varscan2
- GNAS | c.650G>A p.S217N | Missense Mutation (SNP) | VAF 3/8 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV58339588; called by muse, mutect2
- GNB4 | c.758T>G p.F253C | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51710398; called by muse, mutect2, varscan2
- GPALPP1 | c.731C>T p.S244F | Missense Mutation (SNP) | VAF 43/109 reads (39%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV62706111; called by muse, mutect2, varscan2
- GPATCH3 | c.686C>T p.S229F | Missense Mutation (SNP) | VAF 33/107 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV64652297; called by muse, mutect2, varscan2
- GPC5 | c.220G>A p.E74K | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65609683; called by muse, mutect2, varscan2
- GPER1 | c.134G>A p.G45E | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV52469622; called by muse, mutect2, varscan2
- GPR148 | c.621G>A p.M207I | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV59308692; called by muse, mutect2, varscan2
- GPR149 | c.1667G>A p.G556E | Missense Mutation (SNP) | VAF 35/108 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67668220; called by muse, mutect2, varscan2
- GPR162 | c.395A>G p.K132R | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT tolerated (0.14); PolyPhen benign (0.226); catalogued as COSV50592455; called by muse, mutect2, varscan2
- GPR35 | c.536G>A p.G179E | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.596); catalogued as COSV60577763; called by muse, mutect2, varscan2
- GRIA1 | c.2271-1G>A p.X757_splice | Splice Site (SNP) | VAF 11/21 reads (52%) | catalogued as COSV99602714; called by muse, mutect2, varscan2
- GRK3 | c.1899A>T p.Q633H | Missense Mutation (SNP) | VAF 29/97 reads (30%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.919); catalogued as COSV100152104; called by muse, mutect2, varscan2
- GYS2 | c.332G>A p.G111E | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53925252; called by muse, mutect2, varscan2
- HACD3 | c.753G>A p.W251* | Nonsense Mutation (SNP) | VAF 19/63 reads (30%) | catalogued as COSV56011942; called by muse, mutect2, varscan2
- HACL1 | c.1622C>T p.S541F | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.74); catalogued as COSV100337433; called by muse, mutect2, varscan2
- HADHB | c.607C>T p.R203* | Nonsense Mutation (SNP) | VAF 19/67 reads (28%) | catalogued as rs534616210, CM031204, COSV58544605; called by muse, mutect2, varscan2
- HAO1 | c.299C>T p.S100F | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.033); catalogued as COSV66492637; called by muse, mutect2, varscan2
- HBG2 | c.179A>C p.K60T | Missense Mutation (SNP) | VAF 21/96 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as COSV57963951; called by muse, mutect2, varscan2
- HDAC5 | c.695C>T p.P232L | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs1377619054, COSV56820100; called by muse, mutect2, varscan2
- HDAC9 | c.1249C>T p.P417S | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.191); catalogued as COSV67767795; called by muse, varscan2
- HDDC2 | c.349C>T p.L117F | Missense Mutation (SNP) | VAF 44/76 reads (58%) | SIFT tolerated (0.1); PolyPhen benign (0.026); catalogued as COSV59532569; called by muse, mutect2, varscan2
- HECW2 | c.1354C>T p.P452S | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as COSV53664896, COSV99647231; called by muse, mutect2, varscan2
- HERC2 | c.263C>T p.P88L | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs374189356, COSV55311580; called by muse, mutect2, varscan2
- HERC5 | c.1177G>A p.E393K | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.184); catalogued as rs1206625081, COSV52040881; called by mutect2, varscan2
- HHLA2 | c.305G>A p.G102E | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.823); catalogued as COSV63318197; called by muse, mutect2, varscan2
- HIVEP2 | c.4762C>T p.P1588S | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT tolerated (0.69); PolyPhen benign (0.001); catalogued as COSV50022367; called by muse, mutect2, varscan2
- HKDC1 | c.2306G>A p.G769E | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100664844; called by muse, mutect2, varscan2
- HLA-A | c.208G>A p.E70K | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.997); catalogued as rs199474400, COSV65142339; called by muse, mutect2, varscan2
- HMCN1 | c.6542G>A p.G2181E | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54914668; called by muse, mutect2, varscan2
- HMGCL | c.61G>A p.V21I | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.001); catalogued as COSV52526570; called by muse, mutect2, varscan2
- HRNR | c.850G>A p.G284S | Missense Mutation (SNP) | VAF 51/162 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.037); catalogued as COSV64259941; called by muse, mutect2, varscan2
- HS3ST2 | c.854T>G p.M285R | Missense Mutation (SNP) | VAF 26/125 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV54464496; called by muse, mutect2, varscan2
- HS3ST6 | c.649G>A p.D217N | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.3); PolyPhen benign (0.216); catalogued as COSV99562919; called by muse, mutect2
- HSPA6 | c.1399C>T p.P467S | Missense Mutation (SNP) | VAF 27/59 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as COSV59061625; called by muse, varscan2
- IGF2BP1 | c.1567G>A p.V523I | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT tolerated (0.17); PolyPhen benign (0.399); catalogued as COSV51733150; called by muse, mutect2, varscan2
- IGFN1 | c.3607G>A p.V1203M (on ENST00000295591 / NM_001367841.1; = p.V3660M on NM_001164586.2) | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.076); catalogued as COSV55188863; called by muse, varscan2
- IGKV1-8 | c.190C>T p.P64S | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as rs1176907148; called by muse, mutect2, varscan2
- IGLV3-16 | c.224G>A p.G75E | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.774); catalogued as rs1251907565; called by muse, mutect2, varscan2
- IGSF10 | c.2315G>A p.R772Q | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs746715734, COSV56787782; called by muse, mutect2, varscan2
- ILKAP | c.1000C>T p.P334S | Missense Mutation (SNP) | VAF 44/128 reads (34%) | SIFT tolerated (0.32); PolyPhen benign (0.145); catalogued as rs1349617802, COSV99611233; called by muse, mutect2, varscan2
- INPP5D | c.1259A>C p.K420T (on ENST00000445964 / NM_001017915.3; = p.K419T on NM_005541.5) | Missense Mutation (SNP) | VAF 50/106 reads (47%) | SIFT tolerated (0.05); PolyPhen benign (0.057); catalogued as COSV64038272; called by muse, mutect2, varscan2
- IQCH | c.1157G>A p.R386K | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.584); catalogued as COSV60055786; called by muse, mutect2, varscan2
- IRS4 | c.185C>T p.S62F | Missense Mutation (SNP) | VAF 14/18 reads (78%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.615); catalogued as rs776473962, COSV64534611; called by muse, mutect2, varscan2
- ITGAV | c.1178C>T p.P393L | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.205); catalogued as COSV53714910; called by muse, mutect2, varscan2
- ITIH1 | c.671C>T p.S224F | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV56258070, COSV99835690; called by muse, mutect2
- ITPR1 | c.3256C>T p.R1086W (on ENST00000354582; = p.R1071W on NM_002222.7) | Missense Mutation (SNP) | VAF 25/38 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs752791333, COSV56981343, COSV56991339; called by muse, mutect2, varscan2
- JKAMP | c.7G>A p.G3R | Missense Mutation (SNP) | VAF 37/96 reads (39%) | SIFT tolerated, low confidence (0.23); PolyPhen possibly damaging (0.632); catalogued as COSV99711803; called by muse, mutect2, varscan2
- JKAMP | c.8G>A p.G3E | Missense Mutation (SNP) | VAF 37/97 reads (38%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.029); catalogued as COSV99711805; called by muse, mutect2, varscan2
- KALRN | c.6488G>A p.G2163E (on ENST00000360013 / NM_001024660.4; = p.G466E on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as COSV52259758; called by muse, mutect2, varscan2
- KANSL1L | c.382C>T p.H128Y | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.271); catalogued as COSV55993875; called by muse, varscan2
- KCNA2 | c.113A>G p.N38S | Missense Mutation (SNP) | VAF 111/188 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60370746; called by muse, mutect2, varscan2
- KCNB2 | c.2459G>A p.G820E | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.093); catalogued as rs1272340113, COSV73049101; called by muse, mutect2, varscan2
- KCNJ3 | c.137T>C p.F46S | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV54539126; called by muse, mutect2, varscan2
- KCNK1 | c.538G>A p.A180T | Missense Mutation (SNP) | VAF 22/39 reads (56%) | SIFT tolerated (0.13); PolyPhen benign (0.255); catalogued as COSV64035546; called by muse, mutect2, varscan2
- KCNS1 | c.1331G>A p.G444E | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.893); catalogued as COSV60260459; called by muse, mutect2, varscan2
- KDM4D | c.1157C>T p.P386L | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs1047122654, COSV58635255; called by muse, mutect2, varscan2
- KDM7A | c.2501C>T p.S834L | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.205); catalogued as COSV50092896; called by muse, mutect2, varscan2
- KHDRBS1 | c.625-1G>A p.X209_splice | Splice Site (SNP) | VAF 16/40 reads (40%) | catalogued as COSV56982641; called by muse, mutect2, varscan2
- KIAA1210 | c.3932C>T p.S1311F | Missense Mutation (SNP) | VAF 67/105 reads (64%) | SIFT tolerated (0.14); PolyPhen benign (0.022); catalogued as COSV68178163; called by muse, mutect2, varscan2
- KIAA1549 | c.5240C>T p.P1747L | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.321); catalogued as COSV54318979; called by muse, mutect2, varscan2
- KIF21B | c.291G>A p.M97I | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV59760889; called by muse, mutect2, varscan2
- KIF26B | c.593C>T p.A198V | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101313820, COSV68572523; called by muse, mutect2, varscan2
- KIF26B | c.1282C>T p.P428S | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); catalogued as COSV63645130; called by muse, mutect2, varscan2
- KIF2B | c.865G>A p.E289K | Missense Mutation (SNP) | VAF 27/52 reads (52%) | SIFT tolerated (0.18); PolyPhen benign (0.173); catalogued as COSV52128292, COSV52130711, COSV52132609; called by muse, mutect2, varscan2
- KIR2DL1 | c.236G>A p.G79E | Missense Mutation (SNP) | VAF 62/198 reads (31%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.761); catalogued as COSV52415054, COSV99383048; called by muse, varscan2
- KIR2DL3 | c.121T>G p.S41A | Missense Mutation (SNP) | VAF 44/234 reads (19%) | SIFT tolerated (0.25); PolyPhen benign (0.031); catalogued as rs1444904673; called by muse, mutect2
- KIRREL2 | c.701C>T p.S234L | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.063); catalogued as rs773812234, COSV52874091; called by muse, mutect2, varscan2
- KLB | c.1404G>A p.W468* | Nonsense Mutation (SNP) | VAF 28/82 reads (34%) | catalogued as rs1415053047, COSV57302800; called by muse, mutect2, varscan2
- KLHL3 | c.466C>T p.R156C | Missense Mutation (SNP) | VAF 9/14 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs139384947; called by muse, mutect2, varscan2
- KLK9 | c.16C>T p.L6F | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV51593104; called by muse, mutect2, varscan2
- KLRK1 | c.70G>A p.D24N | Missense Mutation (SNP) | VAF 9/14 reads (64%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV53699025; called by muse, mutect2, varscan2
- KMT2A | c.7049C>T p.S2350F | Missense Mutation (SNP) | VAF 26/46 reads (57%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.015); catalogued as COSV63288297; called by muse, mutect2, varscan2
- KRT16 | c.1150G>T p.E384* | Nonsense Mutation (SNP) | VAF 46/69 reads (67%) | catalogued as COSV56968761; called by muse, mutect2, varscan2
- LAMA2 | c.7690C>T p.L2564F | Missense Mutation (SNP) | VAF 32/54 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV70350282, COSV70351115, COSV70351952; called by muse, mutect2, varscan2
- LARP4B | c.595C>T p.H199Y | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.744); catalogued as COSV60222163; called by muse, mutect2, varscan2
- LCA5 | c.192C>T p.A64= | Splice Region (SNP) | VAF 51/102 reads (50%) | catalogued as COSV100878397; called by muse, mutect2, varscan2
- LCA5 | c.191C>T p.A64V | Missense Mutation (SNP) | VAF 48/97 reads (49%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as COSV100878399; called by muse, mutect2, varscan2
- LCP2 | c.695C>T p.A232V | Missense Mutation (SNP) | VAF 40/80 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.023); catalogued as COSV50454562; called by muse, mutect2, varscan2
- LILRA1 | c.718G>A p.E240K | Missense Mutation (SNP) | VAF 27/100 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.403); catalogued as COSV52182266; called by muse, mutect2, varscan2
- LILRA2 | c.1040G>T p.R347L | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT tolerated (0.3); PolyPhen benign (0.011); catalogued as COSV52193551; called by mutect2, varscan2
- LILRB4 | c.947G>A p.R316K | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV54404881; called by muse, mutect2, varscan2
- LIPI | c.158C>T p.S53F | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1457787148, COSV60708632; called by muse, mutect2, varscan2
- LPAR1 | c.590A>G p.N197S | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT tolerated (0.58); PolyPhen benign (0.055); catalogued as COSV62689821; called by muse, mutect2, varscan2
- LPAR4 | c.434G>A p.R145Q | Missense Mutation (SNP) | VAF 26/49 reads (53%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.689); catalogued as rs1287530585, COSV70912494; called by muse, mutect2, varscan2
- LPIN1 | c.1166G>A p.S389N | Missense Mutation (SNP) | VAF 76/225 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.014); catalogued as COSV56767390; called by muse, mutect2, varscan2
- LRP1B | c.13124G>A p.S4375N | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV67243723, COSV67289229; called by muse, mutect2, varscan2
- LRP1B | c.4207C>T p.R1403C | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs373336223; called by muse, mutect2, varscan2
- LRP2 | c.12161C>T p.P4054L | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.935); catalogued as rs1184853391, COSV99790762; called by muse, mutect2, varscan2
- LRP2 | c.12160C>T p.P4054S | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.874); catalogued as COSV55565765; called by muse, mutect2, varscan2
- LRP2 | c.1522A>G p.N508D | Missense Mutation (SNP) | VAF 39/109 reads (36%) | SIFT tolerated (0.05); PolyPhen benign (0.011); catalogued as COSV55560728; called by muse, mutect2, varscan2
- LRP5 | c.4837G>A p.D1613N | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs776196884, COSV99592821; called by muse, mutect2, varscan2
- LRRC27 | c.1480C>G p.R494G | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs199929957, COSV63996326; called by muse, mutect2, varscan2
- LRRC30 | c.94G>A p.D32N | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.829); catalogued as COSV67301353; called by muse, mutect2, varscan2
- LRRC66 | c.2587C>T p.P863S | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0.386); catalogued as rs776170857, COSV100603030, COSV58634946; called by muse, mutect2, varscan2
- LRRIQ1 | c.2143T>G p.C715G | Missense Mutation (SNP) | VAF 76/245 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV67833587; called by muse, mutect2, varscan2
- LRRIQ1 | c.3515G>A p.R1172Q | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as rs775680245, COSV67831579, COSV67833594; called by muse, mutect2, varscan2
- LRRIQ3 | c.1639G>A p.E547K | Missense Mutation (SNP) | VAF 35/83 reads (42%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV63046139; called by muse, mutect2, varscan2
- LRRN2 | c.1225C>T p.R409C | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs141763834; called by muse, mutect2, varscan2
- LSM14A | c.320C>T p.S107F | Missense Mutation (SNP) | VAF 39/131 reads (30%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.982); catalogued as COSV70885368; called by muse, mutect2, varscan2
- MACC1 | c.526G>A p.E176K | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs1489376803, COSV60544388, COSV60545734; called by muse, mutect2, varscan2
- MACF1 | c.21619C>T p.Q7207* (on ENST00000372915; = p.Q5252* on NM_012090.5) | Nonsense Mutation (SNP) | VAF 13/44 reads (30%) | catalogued as COSV99247519; called by muse, mutect2, varscan2
- MAGEC1 | c.1491T>G p.S497R | Missense Mutation (SNP) | VAF 62/90 reads (69%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.093); catalogued as COSV53576325; called by muse, mutect2, varscan2
- MAMDC2 | c.2047G>A p.E683K | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV65857773; called by muse, mutect2, varscan2
- MAN1C1 | c.956G>A p.G319D | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV56046350; called by mutect2, varscan2
- MAP3K4 | c.3448C>T p.R1150C | Missense Mutation (SNP) | VAF 19/35 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs747914971, COSV62335605; called by muse, mutect2, varscan2
- MAP3K9 | c.2566G>A p.E856K (on ENST00000554752 / NM_001284230.1; = p.E870K on NM_033141.4) | Missense Mutation (SNP) | VAF 14/23 reads (61%) | SIFT deleterious (0.02); PolyPhen benign (0.027); catalogued as COSV67121965; called by muse, mutect2, varscan2
- MAP7D1 | c.1474C>T p.P492S | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.996); catalogued as COSV100294560, COSV60217160; called by muse, mutect2, varscan2
- MAPK1 | c.725-1G>A p.X242_splice | Splice Site (SNP) | VAF 23/81 reads (28%) | catalogued as COSV53187454; called by muse, mutect2, varscan2
- MAPK7 | c.2087C>T p.A696V | Missense Mutation (SNP) | VAF 23/39 reads (59%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as COSV55191039; called by muse, mutect2, varscan2
- MARCHF10 | c.2377G>A p.E793K | Missense Mutation (SNP) | VAF 31/113 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.651); catalogued as COSV60888842; called by muse, mutect2, varscan2
- MASP1 | c.1763G>A p.G588D | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61828284; called by muse, mutect2, varscan2
- MBTPS1 | c.427C>T p.P143S | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV58571562; called by muse, mutect2, varscan2
- MCM5 | c.1793G>A p.R598K | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT tolerated (0.59); PolyPhen benign (0.012); catalogued as COSV99332091; called by muse, mutect2, varscan2
- MCUB | c.379G>A p.D127N | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.678); catalogued as COSV67120444; called by mutect2, varscan2
- MDC1 | c.1471C>T p.P491S | Missense Mutation (SNP) | VAF 46/91 reads (51%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV64525288; called by muse, mutect2, varscan2
- ME1 | c.613G>A p.D205N | Missense Mutation (SNP) | VAF 25/40 reads (63%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.954); catalogued as rs1200239613, COSV63840513; called by muse, mutect2, varscan2
- MEF2D | c.755C>T p.P252L | Missense Mutation (SNP) | VAF 29/58 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.051); catalogued as rs760467482, COSV61728172; called by muse, mutect2, varscan2
- MEFV | c.382G>A p.E128K | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated (0.2); PolyPhen benign (0.403); catalogued as rs368981831; called by muse, mutect2, varscan2
- MEPCE | c.1825C>T p.P609S | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.672); catalogued as rs755809918, COSV99440283; called by muse, mutect2, varscan2
- MEPCE | c.1826C>T p.P609L | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as COSV99440284; called by muse, mutect2, varscan2
- MGAM | c.4222C>T p.P1408S | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.125); catalogued as COSV72074851, COSV72075011; called by muse, mutect2, varscan2
- MGP | c.199G>A p.E67K | Missense Mutation (SNP) | VAF 111/188 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs550754490, COSV57454627; called by muse, mutect2, varscan2
- MICAL1 | c.1592C>T p.S531F | Missense Mutation (SNP) | VAF 21/40 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.121); catalogued as COSV57806015; called by muse, mutect2, varscan2
- MICALL1 | c.380C>T p.P127L | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs767394714, COSV53241669; called by muse, mutect2, varscan2
- MLIP | c.1003C>T p.R335C | Missense Mutation (SNP) | VAF 25/33 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs138048655, COSV51430814; called by muse, mutect2, varscan2
- MMP9 | c.655C>T p.P219S | Missense Mutation (SNP) | VAF 83/240 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.235); catalogued as COSV63434108; called by muse, mutect2, varscan2
- MOCS3 | c.1280C>T p.S427F | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.563); catalogued as COSV54866975; called by muse, mutect2, varscan2
- MOV10L1 | c.377C>T p.S126F | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV53174500; called by muse, mutect2, varscan2
- MROH9 | c.879G>A p.M293I | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.805); catalogued as rs1403128000, COSV63012201; called by muse, mutect2, varscan2
- MRPL58 | c.259C>T p.P87S | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100043074; called by muse, mutect2, varscan2
- MRPL58 | c.260C>T p.P87L | Missense Mutation (SNP) | VAF 21/41 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100043075; called by muse, mutect2, varscan2
- MRPS31 | c.950A>T p.N317I | Missense Mutation (SNP) | VAF 33/89 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60267532; called by muse, mutect2, varscan2
- MS4A10 | c.346T>A p.S116T | Missense Mutation (SNP) | VAF 37/132 reads (28%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.506); catalogued as rs774302210, COSV57633022; called by muse, mutect2, varscan2
- MS4A2 | c.538G>A p.E180K | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.452); catalogued as COSV54012973; called by muse, mutect2, varscan2
- MSH4 | c.41C>T p.P14L | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as rs776300900, COSV54204113; called by muse, mutect2, varscan2
- MTERF4 | c.232C>T p.L78F | Missense Mutation (SNP) | VAF 31/72 reads (43%) | SIFT tolerated (0.5); PolyPhen benign (0.055); catalogued as COSV54089876; called by muse, mutect2, varscan2
- MTMR11 | c.706C>T p.P236S (on ENST00000439741 / NM_001145862.2; = p.P164S on NM_181873.3) | Missense Mutation (SNP) | VAF 35/98 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63807136; called by muse, mutect2, varscan2
- MTR | c.1870C>T p.H624Y | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.044); catalogued as COSV63965547; called by muse, mutect2, varscan2
- MUC16 | c.33277G>A p.G11093R | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.068); catalogued as rs536198753, COSV67477113; called by muse, mutect2, varscan2
- MUC16 | c.25918C>T p.H8640Y | Missense Mutation (SNP) | VAF 31/64 reads (48%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.031); catalogued as COSV67477120; called by muse, mutect2, varscan2
- MUC16 | c.17269G>A p.D5757N | Missense Mutation (SNP) | VAF 41/104 reads (39%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.917); catalogued as rs910009324, COSV67477126; called by muse, mutect2, varscan2
- MUC16 | c.4924G>A p.G1642R | Missense Mutation (SNP) | VAF 28/103 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.111); catalogued as COSV67477133; called by muse, mutect2, varscan2
- MUC16 | c.1636G>A p.E546K | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.801); catalogued as COSV67477137; called by muse, mutect2, varscan2
- MYBPC2 | c.573G>A p.R191= | Splice Region (SNP) | VAF 5/20 reads (25%) | catalogued as rs568422087; called by mutect2, varscan2
- MYBPC2 | c.574G>A p.E192K | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.006); catalogued as COSV63097112; called by muse, mutect2, varscan2
- MYH15 | c.164G>A p.W55* | Nonsense Mutation (SNP) | VAF 26/79 reads (33%) | catalogued as rs765150954, COSV56313807; called by muse, mutect2, varscan2
- MYH8 | c.2430G>A p.R810= | Splice Region (SNP) | VAF 24/45 reads (53%) | catalogued as rs1478940960, COSV67967922; called by muse, mutect2, varscan2
- MYL10 | c.670G>A p.E224K | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.952); catalogued as rs147592822, COSV56208255; called by muse, mutect2, varscan2
- MYLPF | c.304G>A p.G102R | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.119); catalogued as rs775353015, COSV58442789; called by muse, mutect2, varscan2
- MYO1H | c.1678G>A p.E560K | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.42); PolyPhen benign (0.341); catalogued as COSV60447693; called by muse, mutect2, varscan2
- MYO3A | c.4543C>T p.H1515Y | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs267602453, COSV56330015; called by mutect2, varscan2
- MYO5B | c.601C>T p.P201S | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV53220340; called by muse, mutect2, varscan2
- MYO7A | c.1070C>T p.S357F | Missense Mutation (SNP) | VAF 31/75 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.118); catalogued as rs973301416, COSV68685432; called by muse, mutect2, varscan2
- MYOM1 | c.3520G>A p.D1174N | Missense Mutation (SNP) | VAF 54/159 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV55295102, COSV55297857; called by muse, mutect2, varscan2
- NAA11 | c.84G>A p.M28I | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.067); catalogued as COSV54514464; called by muse, mutect2, varscan2
- NAA40 | c.107G>A p.G36E | Missense Mutation (SNP) | VAF 31/79 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1261480899, COSV58161422; called by muse, mutect2, varscan2
- NAV3 | c.458G>A p.G153E | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57092246; called by muse, mutect2, varscan2
- NBEA | c.8642G>A p.G2881E | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV59786753; called by muse, mutect2, varscan2
- NCAM2 | c.2122G>A p.G708R | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.621); catalogued as COSV53081204, COSV53085980; called by muse, mutect2, varscan2
- NDST2 | c.749C>T p.P250L | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV55216073; called by muse, mutect2, varscan2
- NECTIN3 | c.1292G>C p.R431T | Missense Mutation (SNP) | VAF 36/95 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.738); catalogued as COSV100162572, COSV60552207; called by muse, varscan2
- NECTIN3 | c.1334C>T p.P445L | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.795); catalogued as COSV60552213; called by muse, varscan2
- NEK7 | c.776C>T p.P259L | Missense Mutation (SNP) | VAF 42/122 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.873); catalogued as COSV66315414; called by muse, mutect2, varscan2
- NEUROD6 | c.307G>A p.E103K | Missense Mutation (SNP) | VAF 50/178 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV51771348; called by muse, mutect2, varscan2
- NFATC2 | c.2450A>G p.N817S | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV65357887; called by muse, mutect2, varscan2
- NFATC4 | c.1295A>G p.H432R | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs762172509, COSV51606125; called by muse, mutect2, varscan2
- NIN | c.3085C>T p.L1029F | Missense Mutation (SNP) | VAF 95/158 reads (60%) | SIFT tolerated (0.8); PolyPhen benign (0.012); catalogued as COSV55396589; called by muse, mutect2, varscan2
- NKAIN2 | c.334G>A p.G112R | Missense Mutation (SNP) | VAF 23/44 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV63672776; called by muse, mutect2, varscan2
- NLRP13 | c.1246G>A p.E416K | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs544413027, COSV61619947; called by muse, mutect2, varscan2
- NLRP4 | c.1034G>A p.W345* | Nonsense Mutation (SNP) | VAF 20/53 reads (38%) | catalogued as COSV56717123; called by muse, mutect2, varscan2
- NLRP7 | c.2760G>A p.W920* (on ENST00000340844 / NM_206828.3; = p.W892* on NM_139176.3) | Nonsense Mutation (SNP) | VAF 29/92 reads (32%) | catalogued as rs932369211, COSV60171453; called by muse, mutect2, varscan2
- NLRP8 | c.2080G>A p.D694N | Missense Mutation (SNP) | VAF 38/117 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.764); catalogued as COSV52590108, COSV52591703; called by muse, mutect2
- NMS | c.17C>T p.P6L | Missense Mutation (SNP) | VAF 32/114 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.019); catalogued as COSV65258925; called by muse, mutect2, varscan2
- NOL4 | c.709G>A p.D237N | Missense Mutation (SNP) | VAF 18/28 reads (64%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.991); catalogued as COSV52339495, COSV52352073, COSV52358887; called by muse, mutect2, varscan2
- NOS1 | c.2024G>A p.G675E | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57615770; called by muse, mutect2, varscan2
- NOX1 | c.1076G>A p.G359E | Missense Mutation (SNP) | VAF 24/29 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54195303; called by muse, mutect2, varscan2
- NPAP1 | c.230C>T p.A77V | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.839); catalogued as rs1233650819, COSV61508586; called by muse, mutect2, varscan2
- NPAP1 | c.497C>T p.P166L | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT tolerated (0.65); PolyPhen benign (0.169); catalogued as rs752923324, COSV61505391, COSV61510583; called by muse, mutect2
- NPTXR | c.1066C>T p.H356Y | Missense Mutation (SNP) | VAF 34/77 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.376); catalogued as COSV60728787; called by muse, mutect2, varscan2
- NPY1R | c.986G>A p.R329K | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56713253; called by muse, mutect2, varscan2
- NR4A3 | c.127G>A p.G43S | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (0.64); PolyPhen benign (0.001); catalogued as COSV58246298; called by muse, mutect2, varscan2
- NRAP | c.4841G>A p.R1614K (on ENST00000359988 / NM_001322945.2; = p.R1579K on NM_006175.4) | Missense Mutation (SNP) | VAF 21/96 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV63491667; called by muse, mutect2, varscan2
- NSD1 | c.103G>A p.G35S | Missense Mutation (SNP) | VAF 34/60 reads (57%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.466); catalogued as rs777455412, COSV61778905; called by muse, mutect2, varscan2
- OAT | c.341C>T p.A114V | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.41); catalogued as COSV64347872; called by muse, mutect2, varscan2
- OBSCN | c.3347C>A p.S1116Y | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.793); catalogued as COSV52792045; called by muse, mutect2, varscan2
- OLFM3 | c.29C>T p.A10V | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); catalogued as COSV58800663; called by muse, mutect2, varscan2
- OR10H3 | c.271C>T p.R91C | Missense Mutation (SNP) | VAF 81/380 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as rs763626340, COSV59944126; called by muse, mutect2, varscan2
- OR11H12 | c.500G>A p.G167E | Missense Mutation (SNP) | VAF 38/405 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs534573876, COSV73569043; called by muse, mutect2
- OR1E1 | c.737C>T p.S246F | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT deleterious (0.04); PolyPhen benign (0.213); catalogued as COSV59459220; called by muse, mutect2, varscan2
- OR1Q1 | c.763C>T p.L255F | Missense Mutation (SNP) | VAF 30/77 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV52918385; called by muse, mutect2, varscan2
- OR1S2 | c.625G>A p.E209K | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.338); catalogued as COSV56919714; called by muse, mutect2, varscan2
- OR2A2 | c.506G>A p.G169E | Missense Mutation (SNP) | VAF 31/73 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs1249518515, COSV68871933; called by muse, mutect2, varscan2
- OR2B11 | c.244G>A p.V82I | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT tolerated (0.33); PolyPhen benign (0.046); catalogued as COSV59510649; called by muse, mutect2, varscan2
- OR2C3 | c.526G>A p.D176N | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT tolerated (0.11); PolyPhen benign (0.435); catalogued as rs369782347; called by mutect2, varscan2
- OR2L8 | c.905G>A p.R302Q | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.06); catalogued as rs377182490, COSV61725763; called by muse, mutect2, varscan2
- OR2M3 | c.207G>A p.M69I | Missense Mutation (SNP) | VAF 72/247 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.111); catalogued as rs868120650, COSV71758944; called by muse, mutect2, varscan2
- OR2T4 | c.626T>G p.F209C | Missense Mutation (SNP) | VAF 44/129 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); catalogued as rs769101511, COSV63544459; called by muse, mutect2, varscan2
- OR4A15 | c.469C>T p.Q157* | Nonsense Mutation (SNP) | VAF 36/126 reads (29%) | catalogued as COSV59034901; called by muse, mutect2, varscan2
- OR4D6 | c.493C>T p.P165S | Missense Mutation (SNP) | VAF 35/103 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.364); catalogued as COSV55660169; called by muse, mutect2, varscan2
- OR4K5 | c.61C>T p.Q21* | Nonsense Mutation (SNP) | VAF 18/45 reads (40%) | catalogued as rs1392597454, COSV60004147; called by muse, mutect2, varscan2
- OR4N2 | c.334G>A p.G112R | Missense Mutation (SNP) | VAF 43/107 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.09); catalogued as COSV60050111; called by muse, mutect2, varscan2
- OR51I1 | c.119C>T p.S40F | Missense Mutation (SNP) | VAF 25/40 reads (63%) | SIFT deleterious (0); PolyPhen possibly damaging (0.497); catalogued as COSV66507364; called by muse, mutect2, varscan2
- OR52I2 | c.889G>A p.D297N | Missense Mutation (SNP) | VAF 37/82 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.094); catalogued as COSV57045511; called by muse, varscan2
- OR5A2 | c.386A>G p.N129S | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.29); PolyPhen benign (0.012); catalogued as COSV57391378; called by muse, mutect2, varscan2
- OR5D18 | c.646C>T p.L216F | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.35); catalogued as COSV61737784; called by muse, mutect2, varscan2
- OR5M11 | c.436T>A p.F146I | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.57); PolyPhen benign (0.005); catalogued as COSV73141921; called by muse, mutect2, varscan2
- OR5T2 | c.908C>T p.S303F | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.429); catalogued as COSV57589892; called by muse, varscan2
- P3H2 | c.634G>A p.E212K | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (0.38); PolyPhen benign (0.105); catalogued as COSV60023834; called by muse, mutect2
- P4HA1 | c.955C>T p.P319S | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.468); catalogued as COSV54962919; called by muse, mutect2, varscan2
- PADI3 | c.1004C>T p.T335I | Missense Mutation (SNP) | VAF 17/31 reads (55%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.542); catalogued as COSV64934018; called by muse, mutect2, varscan2
- PAGE2B | c.307G>A p.V103M | Missense Mutation (SNP) | VAF 40/65 reads (62%) | SIFT tolerated (1); PolyPhen benign (0.109); catalogued as COSV66611420; called by muse, mutect2, varscan2
- PAQR8 | c.154C>T p.R52C | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs1275207664, COSV62443016; called by muse, mutect2, varscan2
- PARM1 | c.922G>A p.D308N | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs367804546; called by muse, varscan2
- PCDH10 | c.53C>T p.S18F | Missense Mutation (SNP) | VAF 38/101 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.243); catalogued as COSV52098018; called by muse, mutect2, varscan2
- PCDH15 | c.5183G>A p.R1728K | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as COSV57287519, COSV57294981; called by muse, mutect2
- PCDHA12 | c.1124C>T p.S375L | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.788); catalogued as rs1361945795, COSV56487711; called by muse, mutect2, varscan2
- PCDHGA10 | c.900A>T p.K300N | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.026); catalogued as COSV53978915; called by muse, mutect2, varscan2
- PCDHGA6 | c.352C>T p.P118S | Missense Mutation (SNP) | VAF 23/44 reads (52%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.001); catalogued as COSV53978902; called by muse, mutect2, varscan2
- PCED1B | c.574G>A p.E192K | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.025); catalogued as rs867481954, COSV71394830; called by muse, mutect2, varscan2
- PCLO | c.13940G>A p.G4647E | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.826); catalogued as COSV61626986; called by muse, mutect2, varscan2
- PCLO | c.13939G>A p.G4647R | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.15); catalogued as COSV100439343; called by muse, mutect2, varscan2
- PCLO | c.11491C>T p.R3831C | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61626253; called by muse, mutect2, varscan2
- PCLO | c.5975A>T p.K1992M | Missense Mutation (SNP) | VAF 56/174 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV61646577; called by muse, mutect2, varscan2
- PDE1C | c.1211G>A p.R404K | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV58518832; called by muse, mutect2, varscan2
- PDE4DIP | c.1565G>A p.R522K | Missense Mutation (SNP) | VAF 81/222 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV57707226; called by muse, mutect2, varscan2
- PDGFRA | c.1438G>A p.D480N | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as rs746522772, COSV57269054, COSV57270275; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PHC3 | c.1727C>T p.P576L (on ENST00000494943 / NM_001308116.2; = p.P588L on NM_024947.4) | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.205); catalogued as COSV71948980; called by muse, mutect2, varscan2
- PHKA2 | c.544G>A p.G182R | Missense Mutation (SNP) | VAF 15/20 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66054919; called by muse, mutect2, varscan2
- PIBF1 | c.1187G>C p.R396P | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV100411414, COSV58325091; called by muse, mutect2, varscan2
- PKD1L1 | c.848C>T p.A283V | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV56970246; called by muse, mutect2, varscan2
- PLA2G2D | c.181G>A p.D61N | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV64281764; called by muse, mutect2, varscan2
- PLA2G4D | c.1555C>T p.R519W | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs751893544, COSV51819798; called by muse, mutect2, varscan2
- PLA2R1 | c.1571G>A p.G524E | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (0.47); PolyPhen benign (0.01); catalogued as COSV51781767; called by muse, mutect2, varscan2
- PLCB4 | c.526G>A p.G176R | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs868627354, COSV53807367; called by muse, mutect2, varscan2
- PLCB4 | c.1612G>A p.G538S | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT tolerated (0.52); PolyPhen benign (0.156); catalogued as rs552026343, COSV53807386; called by muse, mutect2, varscan2
- PLCL1 | c.385C>T p.R129C | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780511339, COSV70844244; called by muse, mutect2, varscan2
- PLEC | c.9634C>T p.R3212W (on ENST00000322810 / NM_201380.4; = p.R3102W on NM_000445.5) | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs376638828; ClinVar: uncertain significance; called by muse, mutect2
- PLEKHA5 | c.220T>C p.Y74H | Missense Mutation (SNP) | VAF 43/92 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.478); catalogued as COSV54705007; called by muse, mutect2, varscan2
- PLEKHH2 | c.308A>C p.Q103P | Missense Mutation (SNP) | VAF 82/238 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.184); catalogued as rs1451033684, COSV56756889; called by muse, mutect2, varscan2
- PLRG1 | c.314G>A p.G105E | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV57424019; called by muse, mutect2, varscan2
- PLXNA4 | c.2665G>A p.D889N | Missense Mutation (SNP) | VAF 30/68 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.166); catalogued as rs1003358330, COSV58139896; called by muse, mutect2, varscan2
- PMFBP1 | c.709G>A p.E237K | Missense Mutation (SNP) | VAF 52/193 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV52827074; called by muse, mutect2, varscan2
- POLR3A | c.180+2T>G p.X60_splice | Splice Site (SNP) | VAF 22/67 reads (33%) | catalogued as COSV64931397; called by muse, mutect2, varscan2
- POU6F1 | c.1582G>A p.E528K | Missense Mutation (SNP) | VAF 58/159 reads (36%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV61327171; called by muse, mutect2, varscan2
- POU6F2 | c.982C>T p.L328F | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV68875066; called by muse, mutect2, varscan2
- PPARG | c.298C>T p.Q100* (on ENST00000287820 / NM_015869.5; = p.Q70* on NM_005037.7) | Nonsense Mutation (SNP) | VAF 77/141 reads (55%) | catalogued as COSV55143616; called by muse, mutect2, varscan2
- PPFIA2 | c.1009G>A p.E337K | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV61033499, COSV61040212; called by muse, mutect2, varscan2
- PPM1A | c.586G>T p.A196S | Missense Mutation (SNP) | VAF 32/82 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.323); catalogued as COSV57787569; called by muse, mutect2, varscan2
- PPP1R15B | c.1568C>T p.S523F | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.132); catalogued as rs1432252215, COSV65815715; called by muse, mutect2, varscan2
- PPP1R3A | c.2237C>T p.A746V | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as COSV52886066; called by muse, mutect2, varscan2
- PPWD1 | c.1453G>A p.E485K | Missense Mutation (SNP) | VAF 26/51 reads (51%) | SIFT tolerated (0.77); PolyPhen benign (0.034); catalogued as COSV54334370; called by muse, mutect2, varscan2
- PRAMEF15 | c.463C>T p.L155F | Missense Mutation (SNP) | VAF 91/621 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); catalogued as rs1441632021; called by muse, mutect2, varscan2
- PRB2 | c.656G>A p.G219E | Missense Mutation (SNP) | VAF 62/157 reads (39%) | SIFT tolerated (0.54); PolyPhen benign (0.01); catalogued as COSV66983578; called by muse, varscan2
- PRCC | c.491C>T p.P164L | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV99618997; called by muse, mutect2, varscan2
- PRDM12 | c.451G>A p.D151N | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs773763118, COSV53390012; called by muse, varscan2
- PRDM16 | c.2819C>T p.S940F | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.986); catalogued as COSV99579483; called by muse, mutect2
- PRKDC | c.9344C>T p.S3115F | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs753784516; called by muse, mutect2
- PRMT1 | c.922C>T p.P308S | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.255); catalogued as COSV100050334, COSV60196324; called by muse, mutect2, varscan2
- PRNP | c.275G>A p.G92E | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1279036396, COSV65173872; called by muse, mutect2, varscan2
- PROX1 | c.688G>A p.E230K | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.925); catalogued as COSV54780842; called by muse, mutect2, varscan2
- PRRC2A | c.1853C>T p.P618L | Missense Mutation (SNP) | VAF 31/58 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.022); catalogued as rs922882557, COSV101051407; called by muse, mutect2, varscan2
- PRSS48 | c.651G>A p.K217= | Splice Region (SNP) | VAF 12/60 reads (20%) | catalogued as COSV101490190; called by muse, varscan2
- PSD | c.851C>T p.S284F | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV50042475; called by muse, mutect2
- PSMB8 | c.395C>T p.A132V (on ENST00000374882 / NM_148919.4; = p.A128V on NM_004159.5) | Missense Mutation (SNP) | VAF 12/18 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV100841346; called by mutect2, varscan2
- PTCH2 | c.1883C>T p.S628F | Missense Mutation (SNP) | VAF 25/51 reads (49%) | SIFT tolerated (0.1); PolyPhen benign (0.194); catalogued as COSV64711491; called by muse, mutect2, varscan2
- PTCHD1 | c.775G>A p.E259K | Missense Mutation (SNP) | VAF 41/51 reads (80%) | SIFT tolerated (0.73); PolyPhen benign (0.155); catalogued as COSV65061496; called by muse, mutect2, varscan2
- PTCHD4 | c.1795G>A p.D599N | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated (0.97); PolyPhen benign (0.007); catalogued as rs1323744426, COSV59784500; called by muse, mutect2, varscan2
- PTGS2 | c.99G>A p.M33I | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV66570440; called by muse, mutect2, varscan2
- PTPN1 | c.769C>T p.R257W | Missense Mutation (SNP) | VAF 49/134 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1452015420, COSV65407428; called by muse, mutect2, varscan2
- PTPRB | c.4319G>A p.S1440N | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.13); PolyPhen benign (0.043); catalogued as COSV54245732; called by muse, mutect2, varscan2
- PTPRD | c.4628C>T p.P1543L | Missense Mutation (SNP) | VAF 25/45 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.6); catalogued as rs1242333397, COSV61932417; called by muse, mutect2, varscan2
- PTPRT | c.4115G>A p.G1372E | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV61995215; called by muse, mutect2, varscan2
- PWWP3B | c.632A>G p.K211R | Missense Mutation (SNP) | VAF 13/15 reads (87%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.811); catalogued as COSV61800521; called by muse, mutect2, varscan2
- QPRT | c.682-1G>A p.X228_splice | Splice Site (SNP) | VAF 5/12 reads (42%) | catalogued as COSV54880034; called by muse, mutect2, varscan2
- QTRT2 | c.733G>A p.E245K | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.098); catalogued as rs773263838, COSV55560697; called by muse, mutect2, varscan2
- RAB5B | c.589C>T p.R197W | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.586); catalogued as rs377046623; called by muse, mutect2, varscan2
- RAP1B | c.263C>T p.S88F | Missense Mutation (SNP) | VAF 43/191 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.631); catalogued as COSV99164951; called by muse, mutect2, varscan2
- RAPH1 | c.2987C>T p.S996L | Missense Mutation (SNP) | VAF 29/92 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.603); catalogued as rs147887694; called by muse, mutect2, varscan2
- RASGRP3 | c.1959G>A p.W653* (on ENST00000402538 / NM_001349975.2; = p.W652* on NM_015376.2 and 4 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 19/52 reads (37%) | catalogued as rs1428626694, COSV67823070; called by muse, varscan2
- RBBP6 | c.2350C>T p.R784C | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.642); catalogued as rs146591085, COSV60506453; called by muse, mutect2, varscan2
- RDH8 | c.410G>A p.G137E (on ENST00000651512; = p.G117E on NM_015725.4) | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV50675859; called by muse, mutect2, varscan2
- REG4 | c.433G>A p.E145K | Missense Mutation (SNP) | VAF 652/959 reads (68%) | SIFT tolerated (0.41); PolyPhen benign (0.045); catalogued as rs150927973; called by muse, mutect2, varscan2
- RFT1 | c.1103G>A p.G368D | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1030372067, COSV99965646; called by muse, mutect2
- RFT1 | c.1103-1G>A p.X368_splice | Splice Site (SNP) | VAF 6/25 reads (24%) | catalogued as COSV99965649; called by muse, mutect2, varscan2
- RFX4 | c.70G>A p.E24K | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.905); catalogued as rs1259924867, COSV100774337, COSV63504215; called by muse, mutect2, varscan2
- RFX6 | c.1930C>T p.P644S | Missense Mutation (SNP) | VAF 30/50 reads (60%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.922); catalogued as COSV60586723; called by muse, mutect2, varscan2
- RGS3 | c.349A>T p.R117* | Nonsense Mutation (SNP) | VAF 35/75 reads (47%) | catalogued as COSV58282624; called by muse, mutect2, varscan2
- RHOD | c.466G>A p.G156S | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100448115; called by muse, mutect2, varscan2
- RICTOR | c.3184C>T p.L1062F | Missense Mutation (SNP) | VAF 32/64 reads (50%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.731); catalogued as COSV57125109; called by muse, mutect2, varscan2
- RNF10 | c.2123C>T p.P708L | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT tolerated (0.46); PolyPhen benign (0.039); catalogued as rs769203369, COSV58046475; called by muse, mutect2, varscan2
- RNPEPL1 | c.1901C>A p.T634N | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54373165; called by muse, mutect2, varscan2
- ROBO1 | c.3901C>T p.P1301S | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.25); catalogued as COSV71396362; called by muse, mutect2, varscan2
- ROS1 | c.194A>G p.N65S | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs1346089547, COSV63857287; called by muse, mutect2, varscan2
- RP1 | c.4141A>C p.K1381Q | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0.084); catalogued as COSV55120398, COSV99609255; called by muse, mutect2, varscan2
- RPAP1 | c.1937G>C p.R646P | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.875); catalogued as COSV58540635; called by muse, mutect2, varscan2
- RPH3A | c.1070C>T p.S357F (on ENST00000389385 / NM_001143854.2; = p.S353F on NM_014954.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.424); catalogued as rs867320077, COSV66991507; called by muse, varscan2
- RPS4Y2 | c.298C>T p.R100C | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.874); catalogued as rs746235827, COSV56488436; called by muse, mutect2, varscan2
- RSL1D1 | c.1247C>T p.P416L | Missense Mutation (SNP) | VAF 100/291 reads (34%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.946); catalogued as COSV63078064; called by muse, mutect2, varscan2
- RTN2 | c.893C>T p.P298L | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.11); catalogued as COSV55594967; called by muse, mutect2, varscan2
- RYR2 | c.4576G>A p.E1526K | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV63695600, COSV63724025; called by muse, mutect2, varscan2
- RYR2 | c.5353G>A p.D1785N | Missense Mutation (SNP) | VAF 34/91 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.03); catalogued as COSV63695608; called by muse, mutect2, varscan2
- RYR3 | c.464C>T p.A155V | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.754); catalogued as COSV66798113; called by muse, mutect2, varscan2
- RYR3 | c.818G>A p.W273* | Nonsense Mutation (SNP) | VAF 9/26 reads (35%) | catalogued as COSV66798119; called by muse, mutect2, varscan2
- RYR3 | c.7646C>T p.S2549F (on ENST00000389232; = p.S2550F on NM_001036.6) | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV101215169; called by muse, mutect2, varscan2
- SACS | c.4631C>T p.S1544F | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); catalogued as COSV101207849; called by muse, mutect2, varscan2
- SAG | c.524G>A p.R175Q | Missense Mutation (SNP) | VAF 35/85 reads (41%) | SIFT tolerated (0.05); PolyPhen benign (0.39); catalogued as rs763815691, COSV68591483; called by muse, mutect2, varscan2
- SALL4 | c.1187C>T p.S396F | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.018); catalogued as rs756467626, COSV53853860; called by muse, mutect2, varscan2
- SAMD12 | c.326G>A p.R109Q | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs751200165, COSV59050080; called by muse, mutect2, varscan2
- SAMD3 | c.323C>T p.S108F | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.007); catalogued as COSV60776436; called by muse, mutect2, varscan2
- SAMD9 | c.4529C>T p.S1510F | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as COSV66076413; called by mutect2, varscan2
- SCAF1 | c.416C>T p.P139L | Missense Mutation (SNP) | VAF 9/14 reads (64%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV100862343; called by muse, mutect2, varscan2
- SCG3 | c.1187G>A p.G396E | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.012); catalogued as rs774027135, COSV55021923; called by muse, mutect2, varscan2
- SCN11A | c.2945G>A p.R982Q | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT tolerated (0.58); PolyPhen benign (0.013); catalogued as rs562379429, COSV56569373; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SCN4A | c.2888C>T p.S963F | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as rs1291488319, COSV71126796; called by muse, mutect2, varscan2
- SCN4A | c.198G>A p.M66I | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV71127624; called by muse, varscan2
- SCN4A | c.164G>A p.R55Q | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs376523210; ClinVar: uncertain significance; called by muse, varscan2
- SCN7A | c.532G>A p.D178N | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as rs1471284628, COSV69272798; called by muse, mutect2, varscan2
- SCN9A | c.4486C>T p.P1496S (on ENST00000303354; = p.P1485S on NM_002977.3) | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.702); catalogued as COSV57615070; called by muse, mutect2, varscan2
- SELENOO | c.689T>C p.V230A | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV66599575; called by muse, mutect2, varscan2
- SELENOS | c.335G>A p.R112K | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV68011400; called by muse, mutect2
- SEPHS2 | c.1258C>T p.P420S | Missense Mutation (SNP) | VAF 30/62 reads (48%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.889); catalogued as rs965426011, COSV72100782; called by muse, mutect2, varscan2
- SERPINA7 | c.962T>G p.L321W | Missense Mutation (SNP) | VAF 28/45 reads (62%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.887); catalogued as COSV59666376; called by muse, mutect2, varscan2
- SERPINB9 | c.880C>T p.Q294* | Nonsense Mutation (SNP) | VAF 30/129 reads (23%) | catalogued as COSV66233798; called by muse, mutect2, varscan2
- SERPINE2 | c.679C>T p.R227W | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs1204670877, COSV99297146; called by muse, mutect2, varscan2
- SETD1A | c.946G>T p.A316S | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.005); catalogued as rs1401650611, COSV52689645; called by muse, mutect2, varscan2
- SFT2D2 | c.467C>T p.A156V | Missense Mutation (SNP) | VAF 37/103 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.098); catalogued as COSV54799763; called by muse, mutect2, varscan2
- SH2B1 | c.1304C>T p.S435L | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.468); catalogued as rs557776551, COSV59464455; called by muse, mutect2, varscan2
- SHC2 | c.1480C>T p.R494C | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757191912, COSV99199261; called by muse, varscan2
- SHROOM3 | c.1141G>A p.G381S | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.919); catalogued as COSV56033243; called by muse, mutect2, varscan2
- SI | c.374G>A p.G125E | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.46); catalogued as rs542596956, COSV52267136; called by muse, mutect2, varscan2
- SIGLEC14 | c.656G>A p.G219E | Missense Mutation (SNP) | VAF 21/38 reads (55%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.614); catalogued as COSV55781117; called by muse, mutect2, varscan2
- SIRT1 | c.942G>A p.K314= | Splice Region (SNP) | VAF 57/167 reads (34%) | catalogued as COSV53019076, COSV99281787; called by muse, mutect2, varscan2
- SKIDA1 | c.247A>G p.I83V | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as COSV71610971; called by muse, mutect2, varscan2
- SLC10A5 | c.763T>C p.Y255H | Missense Mutation (SNP) | VAF 44/57 reads (77%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.946); catalogued as COSV72828421; called by muse, mutect2, varscan2
- SLC17A6 | c.1135C>T p.L379F | Missense Mutation (SNP) | VAF 45/93 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); catalogued as COSV54138171; called by muse, mutect2, varscan2
- SLC22A6 | c.133C>T p.P45S | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.995); catalogued as COSV64560469; called by muse, mutect2
- SLC24A2 | c.112C>T p.R38* | Nonsense Mutation (SNP) | VAF 34/70 reads (49%) | catalogued as rs754429867, COSV53868585; called by muse, mutect2, varscan2
- SLC25A11 | c.346C>T p.P116S | Missense Mutation (SNP) | VAF 14/23 reads (61%) | SIFT tolerated (0.14); PolyPhen benign (0.021); catalogued as COSV52590249, COSV52591418; called by muse, mutect2, varscan2
- SLC25A13 | c.635C>T p.S212F | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.635); catalogued as rs137944390; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC25A21 | c.814C>T p.P272S | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs149535012, COSV58725543; called by muse, mutect2, varscan2
- SLC2A5 | c.1222C>T p.R408W | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs771183532, COSV66236600; called by muse, mutect2, varscan2
- SLC4A5 | c.1447G>A p.E483K | Missense Mutation (SNP) | VAF 35/53 reads (66%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.997); catalogued as rs749227703, COSV61029827; called by muse, mutect2, varscan2
- SLC5A7 | c.1342A>C p.T448P | Missense Mutation (SNP) | VAF 30/64 reads (47%) | SIFT tolerated (0.26); PolyPhen benign (0.122); catalogued as COSV50894744; called by muse, mutect2, varscan2
- SLC6A17 | c.1534G>A p.V512I | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.917); catalogued as rs780329859, COSV58994532; called by muse, varscan2
- SLC6A3 | c.1757C>T p.S586F | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.019); catalogued as COSV54366094; called by muse, mutect2, varscan2
- SLC6A7 | c.55A>C p.M19L | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as COSV57939206; called by muse, mutect2, varscan2
- SLC8A2 | c.233C>T p.A78V | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.165); catalogued as COSV52640811; called by muse, mutect2
- SLC9A2 | c.1423C>T p.L475= | Splice Region (SNP) | VAF 18/77 reads (23%) | catalogued as rs750817058, COSV52132002; called by muse, mutect2, varscan2
- SLITRK1 | c.1988C>T p.S663F | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV65674498; called by muse, mutect2, varscan2
- SLITRK6 | c.415G>A p.E139K | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs771630878, COSV68390125; called by muse, mutect2, varscan2
- SLX4 | c.2551A>G p.M851V | Missense Mutation (SNP) | VAF 31/82 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.523); catalogued as rs1176054981, COSV53565643; called by muse, mutect2, varscan2
- SNCA | c.419C>T p.A140V | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.017); catalogued as rs781595227, COSV100410304; called by muse, mutect2, varscan2
- SORT1 | c.1507C>T p.P503S | Missense Mutation (SNP) | VAF 98/310 reads (32%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.71); catalogued as COSV56667754; called by muse, mutect2, varscan2
- SP140L | c.935G>C p.G312A | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV54745602; called by muse, mutect2, varscan2
- SPAG17 | c.4199G>A p.G1400E | Missense Mutation (SNP) | VAF 83/125 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60456929; called by muse, mutect2, varscan2
- SPAM1 | c.797A>T p.N266I | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.387); catalogued as COSV56145289; called by muse, mutect2, varscan2
- SPATA18 | c.1325G>A p.G442E | Missense Mutation (SNP) | VAF 53/152 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV54645040, COSV99730004; called by muse, mutect2, varscan2
- SPATA20 | c.2044C>T p.R682C (on ENST00000356488 / NM_001258372.1; = p.R698C on NM_022827.4) | Missense Mutation (SNP) | VAF 36/116 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.676); catalogued as COSV50067821; called by muse, varscan2
- SPATA20 | c.2089C>T p.Q697* (on ENST00000356488 / NM_001258372.1; = p.Q713* on NM_022827.4) | Nonsense Mutation (SNP) | VAF 20/105 reads (19%) | catalogued as COSV50066099, COSV99136923; called by muse, varscan2
- SPHKAP | c.3412G>A p.E1138K | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60884723; called by muse, mutect2, varscan2
- SPON1 | c.2035G>A p.E679K | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); catalogued as COSV59963434; called by muse, mutect2, varscan2
- SPRY1 | c.935C>T p.S312F | Missense Mutation (SNP) | VAF 31/90 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.202); catalogued as rs1211718459, COSV59338742; called by muse, mutect2, varscan2
- SRGAP1 | c.1795G>A p.D599N | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.513); catalogued as rs368173495; called by muse, mutect2, varscan2
- SRGAP3 | c.2393T>A p.I798K | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as COSV64535695; called by muse, mutect2
- SRRD | c.514C>T p.P172S | Missense Mutation (SNP) | VAF 54/129 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV53226810; called by muse, mutect2, varscan2
- SRRM2 | c.1429C>T p.P477S | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs911450633, COSV57068294; called by muse, mutect2, varscan2
- ST18 | c.2537G>A p.R846K | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs746067341, COSV52499664; called by muse, mutect2, varscan2
- STAB1 | c.1505C>T p.P502L | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as COSV100401450, COSV58739431; called by muse, mutect2, varscan2
- STAB2 | c.6337G>A p.G2113R | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1388885909, COSV66348792; called by muse, mutect2, varscan2
- STAG3 | c.2449G>A p.G817R | Missense Mutation (SNP) | VAF 41/117 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.146); catalogued as COSV57932250; called by muse, mutect2, varscan2
- STAT1 | c.1184C>T p.S395F | Missense Mutation (SNP) | VAF 73/187 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV63116701; called by muse, mutect2, varscan2
- STEAP1 | c.620C>T p.A207V | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.999); catalogued as COSV51882139; called by mutect2, varscan2
- STEAP4 | c.709C>T p.R237C | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.855); catalogued as rs769390918, COSV57329004; called by muse, mutect2, varscan2
- STK11 | c.578C>T p.S193F | Missense Mutation (SNP) | VAF 7/11 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58821010; called by muse, mutect2, varscan2
- SULT2A1 | c.203C>T p.S68F | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55765396; called by muse, mutect2, varscan2
- SUPT6H | c.1778C>T p.A593V | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100112899; called by muse, mutect2, varscan2
- SYBU | c.446G>A p.S149N (on ENST00000276646 / NM_001099754.2; = p.S148N on NM_017786.6) | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1322759738, COSV52620271; called by muse, mutect2, varscan2
- SYDE2 | c.3259C>G p.R1087G | Missense Mutation (SNP) | VAF 52/152 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58323974, COSV58324281; called by muse, mutect2, varscan2
- SYNJ1 | c.2511G>C p.K837N | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); catalogued as COSV59151306; called by muse, mutect2, varscan2
- SYNPO2 | c.484C>T p.P162S | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.85); PolyPhen benign (0.023); catalogued as COSV61113592; called by muse, mutect2, varscan2
- SYT12 | c.1042C>T p.P348S | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67354016; called by muse, mutect2, varscan2
- SYT16 | c.247T>C p.S83P | Missense Mutation (SNP) | VAF 22/105 reads (21%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as COSV70855950; called by muse, mutect2, varscan2
- SYT9 | c.1286C>T p.P429L | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.602); catalogued as COSV59621128; called by muse, mutect2, varscan2
- TAF1 | c.5350G>A p.E1784K (on ENST00000373790 / NM_138923.4; = p.E1805K on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/16 reads (88%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.108); catalogued as COSV52117795; called by muse, mutect2, varscan2
- TAT | c.15G>A p.M5I | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.001); catalogued as COSV63533129; called by muse, mutect2, varscan2
- TBXAS1 | c.77C>T p.A26V | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.68); PolyPhen benign (0.003); catalogued as rs777948651, COSV54948570; called by muse, mutect2, varscan2
- TCAF1 | c.224C>T p.P75L | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as COSV100584750; called by muse, mutect2, varscan2
- TCIM | c.14G>A p.R5Q | Missense Mutation (SNP) | VAF 14/22 reads (64%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as rs758408259, COSV59927620; called by muse, mutect2, varscan2
- TDO2 | c.1034C>T p.S345F | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV72542776; called by muse, mutect2, varscan2
- TDRD6 | c.5033C>T p.P1678L | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.858); catalogued as COSV60176700; called by muse, mutect2, varscan2
- TDRKH | c.1114C>T p.R372* | Nonsense Mutation (SNP) | VAF 25/68 reads (37%) | catalogued as rs749386396, COSV58618656; called by muse, mutect2, varscan2
- TECTB | c.166G>A p.G56R | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs767206672, COSV65595782; called by muse, mutect2, varscan2
- TENM2 | c.1462G>A p.D488N (on ENST00000518659 / NM_001122679.2; = p.D256N on NM_001080428.3) | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT tolerated (0.29); PolyPhen benign (0.047); catalogued as rs938410266, COSV101319495; called by muse, mutect2, varscan2
- TENM3 | c.1687C>T p.R563C | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.543); catalogued as rs1189585069, COSV69312685; called by muse, varscan2
- TENM3 | c.4994C>T p.S1665L | Missense Mutation (SNP) | VAF 28/100 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.037); catalogued as COSV69311662, COSV69312693; called by muse, mutect2, varscan2
- TET1 | c.5636C>T p.P1879L | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT tolerated (0.12); PolyPhen benign (0.018); catalogued as rs201665550, COSV65386279; called by muse, varscan2
- TEX11 | c.2314A>G p.K772E (on ENST00000344304; = p.K757E on NM_031276.3) | Missense Mutation (SNP) | VAF 9/14 reads (64%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.607); catalogued as COSV60233506; called by muse, mutect2, varscan2
- TEX11 | c.370-1G>A p.X124_splice (on ENST00000344304; = p.X109_splice on NM_031276.3) | Splice Site (SNP) | VAF 8/8 reads (100%) | catalogued as rs867420357, COSV60233520; called by muse, mutect2, varscan2
- TGFBRAP1 | c.1004G>A p.G335E | Missense Mutation (SNP) | VAF 21/89 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.045); catalogued as COSV99305660; called by muse, mutect2, varscan2
- TGFBRAP1 | c.1003G>A p.G335R | Missense Mutation (SNP) | VAF 21/89 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.066); catalogued as COSV99305665; called by muse, mutect2, varscan2
- THBS3 | c.2615G>A p.R872Q | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.166); catalogued as rs1261376828, COSV58364810; called by muse, mutect2, varscan2
- TICAM1 | c.1100C>T p.P367L | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV50234403; called by muse, mutect2, varscan2
- TICAM2 | c.29C>T p.S10F | Missense Mutation (SNP) | VAF 24/47 reads (51%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.204); catalogued as rs767481611, COSV56694841; called by muse, mutect2, varscan2
- TKTL2 | c.1204G>A p.D402N | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs752918470, COSV54919838; called by muse, mutect2, varscan2
- TLCD3B | c.185C>T p.S62F | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as COSV54227565; called by muse, mutect2, varscan2
- TLL1 | c.1313G>A p.R438K | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV50280615; called by muse, mutect2, varscan2
- TLN2 | c.157C>T p.L53F | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs1160668837, COSV60891723; called by muse, mutect2, varscan2
- TMC4 | c.266C>T p.P89L (on ENST00000617472 / NM_001145303.3; = p.P83L on NM_144686.4) | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.235); catalogued as COSV55476494; called by muse, mutect2, varscan2
- TMEM168 | c.958C>T p.H320Y | Missense Mutation (SNP) | VAF 42/141 reads (30%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.584); catalogued as COSV57180490; called by muse, mutect2, varscan2
- TMEM202 | c.487G>A p.A163T | Missense Mutation (SNP) | VAF 51/177 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV58983015; called by muse, mutect2, varscan2
- TMEM67 | c.1298C>T p.S433F | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.216); catalogued as COSV60041538; called by muse, mutect2, varscan2
- TMPRSS13 | c.1110-1G>A p.X370_splice | Splice Site (SNP) | VAF 14/20 reads (70%) | catalogued as COSV70626752; called by muse, mutect2, varscan2
- TMPRSS13 | c.148C>T p.P50S | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0); catalogued as COSV70626758; called by muse, mutect2, varscan2
- TMTC3 | c.2357A>G p.D786G | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.102); catalogued as rs1176757647, COSV57124734; called by muse, mutect2, varscan2
- TNFSF14 | c.634G>A p.G212R | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.981); catalogued as COSV55591149; called by muse, mutect2, varscan2
- TNN | c.3505G>A p.E1169K | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.053); catalogued as COSV53429555; called by mutect2, varscan2
- TNR | c.2867C>T p.P956L | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99692158; called by muse, mutect2, varscan2
- TNR | c.1576C>T p.P526S | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs868755868, COSV54881708, COSV99689542; called by muse, mutect2, varscan2
- TNR | c.61C>T p.L21F | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT tolerated, low confidence (0.2); PolyPhen probably damaging (0.994); catalogued as COSV54878990, COSV54896663; called by muse, mutect2, varscan2
- TOM1 | c.1300G>A p.E434K | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.034); catalogued as COSV65898557; called by muse, mutect2, varscan2
- TPH1 | c.869C>T p.S290F | Missense Mutation (SNP) | VAF 29/48 reads (60%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.697); catalogued as COSV51458865; called by muse, mutect2, varscan2
- TPO | c.88C>T p.L30F | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as COSV100222476; called by muse, mutect2, varscan2
- TPTE2 | c.1531C>T p.P511S (on ENST00000400230 / NM_199254.2; = p.P434S on NM_130785.3) | Missense Mutation (SNP) | VAF 21/41 reads (51%) | SIFT tolerated (0.21); PolyPhen benign (0.014); catalogued as rs1303879038, COSV55019216, COSV55023983; called by muse, mutect2, varscan2
- TRAK1 | c.2744G>A p.R915Q | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV59644616; called by muse, mutect2, varscan2
- TRAV13-1 | c.223G>A p.E75K | Missense Mutation (SNP) | VAF 73/186 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs751141340; called by muse, mutect2, varscan2
- TRIOBP | c.1814G>C p.R605P | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.162); catalogued as rs202038718, COSV60377877, COSV60380231; called by muse, varscan2
- TRPM3 | c.5113A>G p.S1705G (on ENST00000357533 / NM_001366142.2; = p.S1560G on NM_020952.6) | Missense Mutation (SNP) | VAF 27/106 reads (25%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.428); catalogued as COSV62589284; called by muse, mutect2, varscan2
- TRPM3 | c.3994C>T p.P1332S (on ENST00000357533 / NM_001366142.2; = p.P1187S on NM_020952.6) | Missense Mutation (SNP) | VAF 26/125 reads (21%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.138); catalogued as COSV62589301; called by muse, mutect2, varscan2
- TRPM4 | c.569C>T p.P190L | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV53265314; called by muse, mutect2, varscan2
- TRPM5 | c.1478C>T p.A493V | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs1299006706, COSV50161620, COSV50201220; called by muse, mutect2
- TRRAP | c.10046C>T p.S3349F (on ENST00000359863 / NM_001244580.1; = p.S3320F on NM_003496.3) | Missense Mutation (SNP) | VAF 40/136 reads (29%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.629); catalogued as COSV62850534; called by muse, mutect2, varscan2
- TSC2 | c.2632C>T p.P878S | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs397515077, CM1310697, COSV54761900; ClinVar: not provided / likely benign / uncertain significance / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- TSC2 | c.2633C>T p.P878L | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99555667; called by muse, mutect2
- TSHZ2 | c.882G>A p.M294I | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV61589747; called by muse, mutect2, varscan2
- TSHZ3 | c.3098C>T p.P1033L | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.051); catalogued as rs1267078604, COSV53675560; called by muse, mutect2, varscan2
- TTLL11 | c.878C>T p.T293I | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT tolerated (0.74); PolyPhen benign (0.001); catalogued as COSV58648558; called by muse, mutect2, varscan2
- TTLL5 | c.304G>A p.G102R | Missense Mutation (SNP) | VAF 28/54 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV54037678; called by muse, mutect2, varscan2
- TTLL5 | c.451C>T p.H151Y | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.803); catalogued as COSV54028853; called by muse, mutect2, varscan2
- TTN | c.101411G>A p.G33804E (on ENST00000591111; = p.G26380E on NM_003319.4) | Missense Mutation (SNP) | VAF 36/130 reads (28%) | PolyPhen probably damaging (0.999); catalogued as COSV60168339; called by muse, mutect2, varscan2
- TTN | c.86011G>T p.V28671F (on ENST00000591111; = p.V21247F on NM_003319.4) | Missense Mutation (SNP) | VAF 37/103 reads (36%) | PolyPhen benign (0.063); catalogued as rs750742292, COSV60168358; called by muse, mutect2, varscan2
- TTN | c.82318G>A p.D27440N (on ENST00000591111; = p.D20016N on NM_003319.4) | Missense Mutation (SNP) | VAF 29/80 reads (36%) | PolyPhen benign (0.274); catalogued as rs1559263943, COSV60168379; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTN | c.65737C>T p.P21913S (on ENST00000591111; = p.P14489S on NM_003319.4) | Missense Mutation (SNP) | VAF 66/189 reads (35%) | PolyPhen benign (0.085); catalogued as COSV60168398; called by muse, mutect2, varscan2
- TTN | c.57869G>A p.G19290E (on ENST00000591111; = p.G11866E on NM_003319.4) | Missense Mutation (SNP) | VAF 7/19 reads (37%) | PolyPhen probably damaging (0.986); catalogued as COSV59997416; called by muse, mutect2, varscan2
- TTN | c.44831C>T p.S14944F (on ENST00000591111; = p.S7520F on NM_003319.4) | Missense Mutation (SNP) | VAF 11/39 reads (28%) | PolyPhen probably damaging (0.98); catalogued as COSV60168438; called by muse, mutect2, varscan2
- TTN | c.28249G>A p.G9417R (on ENST00000591111; = p.G8490R on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 45/134 reads (34%) | PolyPhen probably damaging (1); catalogued as COSV60168476; called by muse, mutect2, varscan2
- TTN | c.23881G>A p.G7961R (on ENST00000591111; = p.G7034R on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/36 reads (53%) | PolyPhen probably damaging (0.939); catalogued as rs1406754899, COSV60168482; called by muse, mutect2, varscan2
- TTN | c.12289C>T p.L4097F (on ENST00000591111; = p.L4051F on NM_003319.4) | Missense Mutation (SNP) | VAF 30/78 reads (38%) | catalogued as COSV59922373; called by muse, mutect2, varscan2
- TTN | c.11728A>G p.T3910A (on ENST00000591111; = p.T3864A on NM_003319.4) | Missense Mutation (SNP) | VAF 20/56 reads (36%) | catalogued as COSV100635262; called by muse, mutect2, varscan2
- TTN | c.8806C>T p.H2936Y (on ENST00000591111; = p.H2890Y on NM_003319.4) | Missense Mutation (SNP) | VAF 59/187 reads (32%) | PolyPhen probably damaging (0.994); catalogued as COSV59911634, COSV60366513; called by muse, mutect2, varscan2
- TUBA3C | c.889G>A p.E297K | Missense Mutation (SNP) | VAF 36/105 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.85); catalogued as rs867215111, COSV67139583; called by muse, mutect2, varscan2
- TUBAL3 | c.715G>A p.V239I | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.023); catalogued as COSV66814455; called by muse, mutect2, varscan2
- UBASH3A | c.1781C>T p.S594F | Missense Mutation (SNP) | VAF 41/181 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs748541912, COSV52313978; called by muse, mutect2, varscan2
- UGT1A4 | c.484G>A p.A162T | Missense Mutation (SNP) | VAF 40/139 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1283933646, COSV100531322; called by muse, mutect2, varscan2
- UGT2B11 | c.903A>C p.E301D | Missense Mutation (SNP) | VAF 35/124 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.029); catalogued as COSV71423593; called by muse, mutect2, varscan2
- UGT2B7 | c.1084C>T p.L362F | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as rs1451636751, COSV100535121, COSV59444183; called by muse, mutect2, varscan2
- ULK2 | c.2195A>T p.H732L | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated (0.32); PolyPhen benign (0.006); catalogued as COSV100861054; called by mutect2, varscan2
- UNC13D | c.120C>T p.I40= | Splice Region (SNP) | VAF 11/28 reads (39%) | catalogued as rs1462217837, COSV99257818; called by muse, varscan2
- USF3 | c.5158C>G p.R1720G | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV57069936, COSV57074695; called by muse, mutect2, varscan2
- USH2A | c.11684G>A p.G3895E | Missense Mutation (SNP) | VAF 35/93 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1472714005, CM073407, COSV56393631; called by muse, mutect2, varscan2
- USH2A | c.8776G>A p.E2926K | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT tolerated (0.64); PolyPhen benign (0.039); catalogued as COSV56393642; called by muse, mutect2, varscan2
- USP40 | c.1265A>T p.Q422L | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.272); catalogued as COSV52483537; called by muse, varscan2
- USP40 | c.802C>T p.P268S | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52483559; called by muse, mutect2, varscan2
- USP43 | c.1010C>T p.S337F | Missense Mutation (SNP) | VAF 26/43 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV53304382; called by muse, mutect2, varscan2
- USP54 | c.4571G>A p.G1524E | Missense Mutation (SNP) | VAF 65/192 reads (34%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.061); catalogued as COSV60441139; called by muse, mutect2, varscan2
- VASP | c.952C>T p.P318S | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.99); PolyPhen probably damaging (0.994); catalogued as rs1485042521, COSV55607249; called by muse, varscan2
- WASHC2C | c.3410C>T p.S1137F (on ENST00000336378; = p.S1116F on NM_015262.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 32/119 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as rs1462524493; called by muse, mutect2, varscan2
- WDR48 | c.1969G>A p.V657M | Missense Mutation (SNP) | VAF 33/94 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV56532781; called by muse, mutect2, varscan2
- WDR75 | c.682C>T p.R228C | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1473276423, COSV59105429; called by muse, mutect2, varscan2
- WRN | c.968C>T p.S323L | Missense Mutation (SNP) | VAF 15/24 reads (63%) | SIFT tolerated (0.27); PolyPhen benign (0.212); catalogued as rs369277330, COSV53302808; ClinVar: uncertain significance / not provided; called by muse, mutect2, varscan2
- XIRP2 | c.6577C>T p.P2193S (on ENST00000628543; = p.P2368S on NM_152381.6) | Missense Mutation (SNP) | VAF 30/97 reads (31%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.087); catalogued as COSV54712906; called by muse, mutect2, varscan2
- XPO4 | c.1571C>T p.S524L | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs767666671, COSV55009491, COSV99688191; called by muse, mutect2, varscan2
504 further variants in this file (58 protein-altering or splice-affecting, 421 silent, 25 other) are not listed here.
